Somatic mutation profile of cancer-model specimen HCM-CSHL-0459-C17-85A (3D Organoid; aliquot HCM-CSHL-0459-C17-85A-01D-A79C-36), derived from the primary tumor of HCMI case HCM-CSHL-0459-C17, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Small intestine, NOS; AJCC pathologic stage: Stage I; Tumor grade: G2; Age at diagnosis: 57.4 years (20,980 days).
Specimen HCM-CSHL-0459-C17-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 63886c2e-6f31-4735-9a79-80c546821fbe.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-CSHL-0459-C17-10A (Blood Derived Normal), aliquot HCM-CSHL-0459-C17-10A-01D-A79C-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/364fbf45-4933-44ad-8505-9bab43d2a291

The open-access MAF lists 2,793 somatic variants for this specimen: 2,040 protein-altering or splice-affecting, 670 silent, 83 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 1,586, Silent 670, Frame Shift Del 230, Frame Shift Ins 83, Nonsense Mutation 74, Intron 47, Splice Region 29, In Frame Del 23, 3'UTR 15, Splice Site 12, 3'Flank 6, 5'Flank 6.

Variants (750 of 2,793; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA12 | c.5012del p.N1671Ifs*4 (on ENST00000272895 / NM_173076.3; = p.N1353Ifs*4 on NM_015657.3) | Frame Shift Del (DEL) | VAF 147/352 reads (42%) | catalogued as rs387906285, CD051281; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- ABCD1 | c.1661G>A p.R554H | Missense Mutation (SNP) | VAF 209/210 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs201568579, CM000643; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ARID1A | c.5164C>T p.R1722* | Nonsense Mutation (SNP) | VAF 134/301 reads (45%) | hotspot (GDC flag); catalogued as rs1485978447, COSV61371609; ClinVar: pathogenic; called by muse, mutect2, varscan2
- BMPR2 | c.1371del p.K457Nfs*17 | Frame Shift Del (DEL) | VAF 125/329 reads (38%) | catalogued as rs1085307340; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- BRCA1 | c.668del p.K223Rfs*11 | Frame Shift Del (DEL) | VAF 124/293 reads (42%) | catalogued as rs80357537, CD057384, CS1211735; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- BRCA2 | c.5583del p.V1862* | Frame Shift Del (DEL) | VAF 69/189 reads (37%) | catalogued as rs397507790, COSV66450671; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- ERBB2 | c.2264T>C p.L755S | Missense Mutation (SNP) | VAF 156/353 reads (44%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121913470, COSV54062780, COSV54064269; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ITPR1 | c.508C>T p.R170* | Nonsense Mutation (SNP) | VAF 128/277 reads (46%) | catalogued as rs886058579, COSV56974596; ClinVar: pathogenic / uncertain significance; called by muse, mutect2, varscan2
- KCNMA1 | c.2026del p.Y676Tfs*15 | Frame Shift Del (DEL) | VAF 126/318 reads (40%) | catalogued as rs762705295; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- LZTR1 | c.365C>T p.S122L | Missense Mutation (SNP) | VAF 242/518 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs587777177, CM140924, COSV99301371; ClinVar: pathogenic; called by muse, mutect2, varscan2
- MSH6 | c.2927G>A p.R976H | Missense Mutation (SNP) | VAF 166/380 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs63751113, CM021636, COSV52275309, COSV52291664; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- RAC1 | c.53G>A p.C18Y | Missense Mutation (SNP) | VAF 140/274 reads (51%) | hotspot (GDC flag); SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.955); catalogued as rs1554263326, COSV100640958, COSV61822452, COSV61823434; ClinVar: pathogenic; called by muse, mutect2
- RNF43 | c.394C>T p.R132* | Nonsense Mutation (SNP) | VAF 147/147 reads (100%) | hotspot (GDC flag); catalogued as rs786205215, CM154177, COSV68457376; ClinVar: pathogenic; called by muse, mutect2, varscan2
- RSPH4A | c.1453C>T p.R485* | Nonsense Mutation (SNP) | VAF 183/383 reads (48%) | catalogued as rs1034327724, COSV57633705; ClinVar: pathogenic; called by muse, mutect2, varscan2
- SLC46A1 | c.194dup p.C66Lfs*99 | Frame Shift Ins (INS) | VAF 282/572 reads (49%) | catalogued as rs80338769; ClinVar: pathogenic; called by mutect2, varscan2
- STK11 | c.536C>A p.P179Q | Missense Mutation (SNP) | VAF 232/461 reads (50%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58822445, COSV58825728, COSV58829155; called by mutect2, varscan2
- SYNE1 | c.24284G>A p.R8095H (on ENST00000367255 / NM_182961.4; = p.R8024H on NM_033071.3) | Missense Mutation (SNP) | VAF 111/283 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs119103246, CM075027, COSV54948375; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABCA12 | c.6327dup p.G2110Wfs*3 (on ENST00000272895 / NM_173076.3; = p.G1792Wfs*3 on NM_015657.3) | Frame Shift Ins (INS) | VAF 131/357 reads (37%) | catalogued as rs1204636023; called by mutect2, pindel, varscan2
- ABCA7 | c.3877C>T p.R1293C | Missense Mutation (SNP) | VAF 216/418 reads (52%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.513); catalogued as rs756112727; called by muse, mutect2, varscan2
- ABCA9 | c.1339G>A p.G447R | Missense Mutation (SNP) | VAF 121/268 reads (45%) | SIFT tolerated (0.87); PolyPhen benign (0); catalogued as rs764821055, COSV60622467; called by muse, varscan2
- ABCB1 | c.1399C>T p.R467W | Missense Mutation (SNP) | VAF 203/389 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1387356833, COSV55945226, COSV55959906; called by muse, mutect2, varscan2
- ABCC3 | c.2258G>T p.G753V | Missense Mutation (SNP) | VAF 64/302 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53322960; called by muse, mutect2, varscan2
- ABCD1 | c.1021G>A p.A341T | Missense Mutation (SNP) | VAF 233/348 reads (67%) | SIFT deleterious (0); PolyPhen possibly damaging (0.85); catalogued as rs782492154; called by muse, mutect2, varscan2
- ABCF1 | c.1145G>A p.R382Q (on ENST00000326195 / NM_001025091.2; = p.R344Q on NM_001090.3) | Missense Mutation (SNP) | VAF 156/362 reads (43%) | SIFT deleterious (0.03); PolyPhen benign (0.112); catalogued as rs749772013; called by muse, mutect2, varscan2
- ABCG1 | c.770C>T p.S257L | Missense Mutation (SNP) | VAF 207/422 reads (49%) | SIFT deleterious (0.03); PolyPhen benign (0.189); catalogued as rs564812607; called by muse, mutect2, varscan2
- ABHD14A-ACY1 | c.1396C>T p.R466C | Missense Mutation (SNP) | VAF 194/365 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs144857039; called by muse, mutect2, varscan2
- ABHD8 | c.842C>T p.T281M | Missense Mutation (SNP) | VAF 190/434 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.293); catalogued as rs1257742043; called by muse, mutect2, varscan2
- ABL1 | c.611C>T p.T204M | Missense Mutation (SNP) | VAF 234/485 reads (48%) | SIFT deleterious (0.04); PolyPhen benign (0.071); catalogued as rs370646520, COSV59325808; called by muse, mutect2, varscan2
- ABLIM3 | c.1724A>G p.D575G | Missense Mutation (SNP) | VAF 128/281 reads (46%) | SIFT deleterious (0.04); PolyPhen benign (0.076); catalogued as COSV58642691; called by muse, mutect2, varscan2
- ABO | c.434G>A p.R145H | Missense Mutation (SNP) | VAF 204/501 reads (41%) | SIFT deleterious (0.03); PolyPhen benign (0.091); catalogued as rs377147187; called by muse, mutect2, varscan2
- ABRA | c.1111C>T p.R371* | Nonsense Mutation (SNP) | VAF 157/317 reads (50%) | catalogued as rs765786301; called by muse, mutect2, varscan2
- AC013489.1 | c.61C>T p.R21C | Missense Mutation (SNP) | VAF 193/406 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.826); catalogued as rs780142606; called by muse, mutect2, varscan2
- ACACB | c.7097C>T p.T2366M | Missense Mutation (SNP) | VAF 177/369 reads (48%) | SIFT tolerated (0.09); PolyPhen benign (0.439); catalogued as rs754980151, COSV58131584; called by muse, mutect2, varscan2
- ACADS | c.1186G>A p.E396K | Missense Mutation (SNP) | VAF 202/420 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV54370327; called by muse, mutect2, varscan2
- ACAP3 | c.2117C>T p.P706L | Missense Mutation (SNP) | VAF 228/428 reads (53%) | SIFT deleterious (0); PolyPhen possibly damaging (0.881); catalogued as rs1319532754; called by muse, varscan2
- ACBD3 | c.568del p.R190Gfs*43 | Frame Shift Del (DEL) | VAF 59/212 reads (28%) | catalogued as rs757016425; called by mutect2, varscan2
- ACIN1 | c.3989G>A p.R1330Q | Missense Mutation (SNP) | VAF 288/601 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); catalogued as rs746023844, COSV99399692; called by muse, mutect2, varscan2
- ACO1 | c.844G>A p.G282R | Missense Mutation (SNP) | VAF 31/214 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1328936319, COSV104401460; called by muse, mutect2, varscan2
- ACOT7 | c.811G>A p.V271I (on ENST00000377855 / NM_181864.3; = p.V261I on NM_007274.4) | Missense Mutation (SNP) | VAF 155/314 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as rs781767639; called by muse, mutect2, varscan2
- ACOX3 | c.876C>T p.D292= | Splice Region (SNP) | VAF 138/283 reads (49%) | catalogued as rs751029086; called by muse, mutect2, varscan2
- ACP7 | c.1168G>A p.V390M | Missense Mutation (SNP) | VAF 213/467 reads (46%) | SIFT deleterious (0.03); PolyPhen benign (0.129); catalogued as rs546523874, COSV58700546; called by muse, varscan2
- ACSF3 | c.391G>A p.A131T | Missense Mutation (SNP) | VAF 180/494 reads (36%) | SIFT tolerated (0.56); PolyPhen benign (0.041); catalogued as rs144411003; called by muse, mutect2
- ACSM3 | c.1385G>T p.R462I | Missense Mutation (SNP) | VAF 121/247 reads (49%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.854); catalogued as COSV55503011; called by muse, varscan2
- ACSS1 | c.904A>G p.K302E | Missense Mutation (SNP) | VAF 237/532 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1241493290; called by muse, mutect2, varscan2
- ACTC1 | c.634C>T p.R212C | Missense Mutation (SNP) | VAF 115/250 reads (46%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0); catalogued as rs1437269590, COSV51757644, COSV99291859; called by muse, mutect2, varscan2
- ACTN2 | c.19G>A p.G7S | Missense Mutation (SNP) | VAF 98/257 reads (38%) | SIFT tolerated, low confidence (0.62); PolyPhen benign (0); catalogued as rs1057523721; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ACVR1 | c.484G>A p.V162M | Missense Mutation (SNP) | VAF 152/310 reads (49%) | SIFT tolerated (0.17); PolyPhen benign (0.03); catalogued as rs201452185; ClinVar: benign; called by muse, mutect2, varscan2
- ADAD1 | c.1301G>A p.R434H | Missense Mutation (SNP) | VAF 186/388 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1314917408; called by muse, mutect2, varscan2
- ADAMTS10 | c.203C>T p.T68M | Missense Mutation (SNP) | VAF 241/480 reads (50%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.595); catalogued as rs782813134, COSV54353240; called by muse, mutect2, varscan2
- ADAMTS4 | c.2035G>A p.G679R | Missense Mutation (SNP) | VAF 138/300 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.481); catalogued as rs767813779; called by muse, mutect2, varscan2
- ADAMTSL2 | c.1990G>A p.D664N | Missense Mutation (SNP) | VAF 434/842 reads (52%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.819); catalogued as rs1233835454, COSV63203957; called by muse, varscan2
- ADAMTSL2 | c.2506G>A p.E836K | Missense Mutation (SNP) | VAF 271/620 reads (44%) | SIFT tolerated (0.49); PolyPhen benign (0.131); catalogued as rs886063646, COSV63204764; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ADAMTSL4 | c.356G>A p.R119Q | Missense Mutation (SNP) | VAF 200/443 reads (45%) | SIFT tolerated (0.36); PolyPhen benign (0.003); catalogued as rs201047866; called by muse, mutect2, varscan2
- ADARB1 | c.1601G>A p.R534H (on ENST00000360697 / NM_001346687.2; = p.R494H on NM_001112.4) | Missense Mutation (SNP) | VAF 213/415 reads (51%) | SIFT deleterious (0.03); PolyPhen benign (0.022); catalogued as rs201477864; called by muse, mutect2, varscan2
- ADCY2 | c.56C>T p.A19V | Missense Mutation (SNP) | VAF 221/490 reads (45%) | SIFT tolerated (0.05); PolyPhen benign (0); catalogued as rs767957240; called by muse, mutect2, varscan2
- ADCY2 | c.757G>A p.A253T | Missense Mutation (SNP) | VAF 167/326 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.803); catalogued as COSV100603438; called by muse, mutect2, varscan2
- ADGRD1 | c.1694C>T p.A565V | Missense Mutation (SNP) | VAF 134/359 reads (37%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.447); catalogued as rs1221659296; called by muse, mutect2, varscan2
- ADGRL3 | c.3091del p.V1031Cfs*39 (on ENST00000506720 / NM_001322402.2; = p.V963Cfs*39 on NM_015236.6) | Frame Shift Del (DEL) | VAF 200/458 reads (44%) | catalogued as COSV104438836; called by mutect2, pindel, varscan2
- ADGRL3 | c.4534G>A p.E1512K (on ENST00000506720 / NM_001322402.2; = p.E1401K on NM_015236.6) | Missense Mutation (SNP) | VAF 185/410 reads (45%) | SIFT tolerated, low confidence (0.57); PolyPhen benign (0.228); catalogued as rs751513777, COSV72231753; called by muse, mutect2, varscan2
- ADORA3 | c.346G>A p.V116I | Missense Mutation (SNP) | VAF 114/267 reads (43%) | SIFT tolerated (0.55); PolyPhen benign (0.003); catalogued as rs766923748, COSV53986544; called by muse, mutect2, varscan2
- ADPRS | c.733C>T p.R245C | Missense Mutation (SNP) | VAF 157/343 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as rs1293906648, COSV52882351; called by muse, mutect2, varscan2
- AEBP1 | c.1246C>T p.R416W | Missense Mutation (SNP) | VAF 198/372 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs764745972, COSV56261407; called by muse, mutect2, varscan2
- AFF4 | c.1520G>A p.R507Q | Missense Mutation (SNP) | VAF 181/394 reads (46%) | SIFT tolerated (0.75); PolyPhen benign (0.027); catalogued as rs1312528517; called by muse, mutect2, varscan2
- AGO1 | c.49dup p.L17Pfs*28 | Frame Shift Ins (INS) | VAF 171/324 reads (53%) | catalogued as rs752471592; called by mutect2, varscan2
- AGO4 | c.1577G>A p.R526H | Missense Mutation (SNP) | VAF 86/185 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as rs750167672; called by muse, mutect2, varscan2
- AGRN | c.2719G>A p.E907K | Missense Mutation (SNP) | VAF 252/573 reads (44%) | SIFT tolerated (0.18); PolyPhen benign (0.023); catalogued as COSV101038734; called by muse, mutect2, varscan2
- AGRN | c.3832C>T p.R1278C | Missense Mutation (SNP) | VAF 371/672 reads (55%) | SIFT tolerated (0.08); PolyPhen benign (0.332); catalogued as rs757377436; called by muse, mutect2, varscan2
- AHDC1 | c.1154G>A p.R385Q | Missense Mutation (SNP) | VAF 236/482 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as rs201616346; called by muse, varscan2
- AIFM3 | c.703C>T p.R235C | Missense Mutation (SNP) | VAF 197/442 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs553803201; called by muse, mutect2
- AIPL1 | c.784+4C>T | Splice Region (SNP) | VAF 163/316 reads (52%) | catalogued as rs375600133; called by muse, mutect2, varscan2
- AK9 | c.2097del p.E700Kfs*13 | Frame Shift Del (DEL) | VAF 13/15 reads (87%) | catalogued as rs753010985; called by mutect2, varscan2
- AKAP17A | c.499G>A p.E167K | Missense Mutation (SNP) | VAF 455/456 reads (100%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.776); catalogued as rs775070085, COSV58312051; called by muse, mutect2, varscan2
- AKAP9 | c.6073C>T p.Q2025* (on ENST00000359028; = p.Q1993* on NM_005751.5 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 60/141 reads (43%) | catalogued as rs786205714, COSV62345120; called by muse, mutect2, varscan2
- ALAS2 | c.577G>A p.V193I | Missense Mutation (SNP) | VAF 241/241 reads (100%) | SIFT deleterious (0.04); PolyPhen benign (0.205); catalogued as rs772482624, CM1312006, COSV58190490; ClinVar: likely benign; called by muse, mutect2, varscan2
- ALDH2 | c.979G>A p.V327M | Missense Mutation (SNP) | VAF 246/466 reads (53%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs751980357, COSV55669488; called by muse, mutect2, varscan2
- ALDH3A1 | c.289G>A p.E97K | Missense Mutation (SNP) | VAF 235/442 reads (53%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.577); catalogued as rs750383473, COSV56736817; called by muse, mutect2, varscan2
- ALG10B | c.980del p.L327Wfs*5 | Frame Shift Del (DEL) | VAF 142/378 reads (38%) | catalogued as COSV58145139; called by mutect2, pindel, varscan2
- ALOX5 | c.1373G>A p.R458Q | Missense Mutation (SNP) | VAF 285/549 reads (52%) | SIFT deleterious (0); PolyPhen benign (0.376); catalogued as rs1312171446; called by muse, mutect2, varscan2
- ALOX5 | c.1703C>T p.A568V | Missense Mutation (SNP) | VAF 17/602 reads (3%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.675); catalogued as rs1313352247; called by muse, mutect2
- ALPK2 | c.3733G>A p.A1245T | Missense Mutation (SNP) | VAF 180/365 reads (49%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as rs147290810; called by muse, mutect2, varscan2
- ALPP | c.442G>A p.G148S | Missense Mutation (SNP) | VAF 223/509 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.593); catalogued as rs755793283, COSV101235192; called by muse, mutect2, varscan2
- AMOTL1 | c.1724G>A p.R575Q | Missense Mutation (SNP) | VAF 176/363 reads (48%) | SIFT deleterious (0.04); PolyPhen benign (0.228); catalogued as rs755948371, COSV100504867; called by muse, mutect2, varscan2
- ANGPTL1 | c.617G>A p.R206Q | Missense Mutation (SNP) | VAF 200/428 reads (47%) | SIFT tolerated (0.7); PolyPhen benign (0.031); catalogued as rs367579998; called by muse, mutect2, varscan2
- ANGPTL7 | c.268C>T p.R90C | Missense Mutation (SNP) | VAF 172/393 reads (44%) | SIFT deleterious (0.03); PolyPhen benign (0.249); catalogued as rs779740660; called by muse, mutect2, varscan2
- ANGPTL8 | c.523C>T p.R175W | Missense Mutation (SNP) | VAF 136/322 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.725); catalogued as rs781506138; called by muse, mutect2, varscan2
- ANK1 | c.784G>A p.G262R | Missense Mutation (SNP) | VAF 131/264 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as COSV55871816; called by muse, mutect2, varscan2
- ANK2 | c.3367G>A p.G1123S | Missense Mutation (SNP) | VAF 113/251 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs138381417; called by muse, mutect2, varscan2
- ANK3 | c.6778G>A p.G2260S | Missense Mutation (SNP) | VAF 135/286 reads (47%) | SIFT tolerated, low confidence (0.85); PolyPhen benign (0); catalogued as rs192587828, COSV99778504; called by muse, mutect2, varscan2
- ANKH | c.406G>A p.A136T | Missense Mutation (SNP) | VAF 120/278 reads (43%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.996); catalogued as rs764910926; called by muse, mutect2, varscan2
- ANKLE1 | c.1465C>T p.Q489* (on ENST00000394458; = p.Q435* on NM_152363.6) | Nonsense Mutation (SNP) | VAF 145/344 reads (42%) | catalogued as rs560635345; called by muse, mutect2, varscan2
- ANKRD11 | c.533G>A p.R178H | Missense Mutation (SNP) | VAF 259/546 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56369004; called by muse, mutect2, varscan2
- ANKRD20A1 | c.598C>T p.R200W | Missense Mutation (SNP) | VAF 32/213 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.664); catalogued as rs1306225598; called by muse, mutect2, varscan2
- ANKRD27 | c.2335G>A p.V779I | Missense Mutation (SNP) | VAF 178/421 reads (42%) | SIFT deleterious (0.04); PolyPhen benign (0.207); catalogued as rs759978285; called by muse, varscan2
- ANKRD31 | c.1451G>A p.R484Q | Missense Mutation (SNP) | VAF 110/253 reads (43%) | SIFT deleterious (0.04); PolyPhen benign (0.281); catalogued as rs1399754846; called by muse, varscan2
- ANKRD36B | c.2066C>T p.T689M | Missense Mutation (SNP) | VAF 90/252 reads (36%) | SIFT tolerated (0.32); PolyPhen benign (0.037); catalogued as rs369666439; called by muse, mutect2, varscan2
- ANKRD44 | c.124C>T p.R42* | Nonsense Mutation (SNP) | VAF 90/196 reads (46%) | catalogued as rs147529433; called by muse, varscan2
- ANP32B | c.579_581del p.E193del | In Frame Del (DEL) | VAF 118/316 reads (37%) | catalogued as rs548651278; called by pindel, varscan2
- ANTKMT | c.686dup p.L230Pfs*? | Frame Shift Ins (INS) | VAF 215/534 reads (40%) | catalogued as rs755358433; called by mutect2, pindel, varscan2
- AOC1 | c.2222del p.P741Lfs*54 | Frame Shift Del (DEL) | VAF 99/428 reads (23%) | catalogued as rs999461756; called by mutect2, pindel, varscan2
- AOX1 | c.182C>A p.P61H | Missense Mutation (SNP) | VAF 58/141 reads (41%) | SIFT tolerated (0.12); PolyPhen benign (0.127); catalogued as COSV65984378; called by mutect2, varscan2
- AP000812.4 | c.154C>T p.R52W | Missense Mutation (SNP) | VAF 233/481 reads (48%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.513); catalogued as rs1372399805, COSV99597694; called by muse, mutect2, varscan2
- AP3D1 | c.1279C>T p.R427W | Missense Mutation (SNP) | VAF 224/436 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs372956453; called by muse, mutect2, varscan2
- AQP3 | c.583G>A p.V195M | Missense Mutation (SNP) | VAF 42/310 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); catalogued as rs756008789; called by muse, mutect2, varscan2
- AQP7 | c.685C>T p.R229W | Missense Mutation (SNP) | VAF 204/275 reads (74%) | SIFT deleterious (0.01); PolyPhen benign (0.296); catalogued as rs780270047, COSV53035946; called by muse, mutect2, varscan2
- ARAF | c.1630C>T p.R544C | Missense Mutation (SNP) | VAF 125/230 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs763351013, COSV51694303; called by muse, mutect2, varscan2
- ARAP1 | c.374C>T p.P125L | Missense Mutation (SNP) | VAF 226/450 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.84); catalogued as rs768446677; called by muse, mutect2, varscan2
- ARC | c.1162G>A p.V388M | Missense Mutation (SNP) | VAF 118/435 reads (27%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.018); catalogued as rs774812713, COSV100751766; called by muse, mutect2, varscan2
- ARFGAP3 | c.669del p.G224Afs*32 | Frame Shift Del (DEL) | VAF 81/249 reads (33%) | catalogued as rs1436718702, COSV54312627; called by mutect2, pindel, varscan2
- ARFGEF3 | c.5599G>A p.A1867T | Missense Mutation (SNP) | VAF 170/375 reads (45%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.23); catalogued as rs766044916, COSV52457823; called by muse, mutect2, varscan2
- ARFIP1 | c.922C>T p.R308C (on ENST00000353617 / NM_001287432.1; = p.R276C on NM_014447.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 97/197 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs367792760; called by muse, mutect2, varscan2
- ARHGAP21 | c.5257G>A p.E1753K | Missense Mutation (SNP) | VAF 196/406 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.59); catalogued as rs771305026, COSV100256084; called by muse, varscan2
- ARHGAP23 | c.2168G>T p.R723L | Missense Mutation (SNP) | VAF 50/666 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.833); catalogued as rs768576450; called by muse, mutect2
- ARHGAP25 | c.1846C>T p.R616C (on ENST00000409202 / NM_001007231.3; = p.R608C on NM_014882.3) | Missense Mutation (SNP) | VAF 234/467 reads (50%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.963); catalogued as rs764265797, COSV54903451; called by muse, mutect2, varscan2
- ARHGAP39 | c.1475G>A p.R492H | Missense Mutation (SNP) | VAF 277/568 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs777563207; called by muse, mutect2, varscan2
- ARHGAP44 | c.198C>T p.S66= | Splice Region (SNP) | VAF 80/204 reads (39%) | catalogued as rs202018989; called by muse, mutect2, varscan2
- ARHGAP45 | c.1943C>A p.S648Y | Missense Mutation (SNP) | VAF 146/328 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV100491023; called by muse, mutect2, varscan2
- ARHGEF11 | c.1597C>T p.R533* | Nonsense Mutation (SNP) | VAF 124/261 reads (48%) | catalogued as COSV63811869; called by muse, mutect2, varscan2
- ARHGEF17 | c.1849C>A p.P617T | Missense Mutation (SNP) | VAF 171/352 reads (49%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0.026); catalogued as rs567330760; called by muse, mutect2, varscan2
- ARHGEF18 | c.2860G>A p.E954K (on ENST00000359920 / NM_001130955.2; = p.E850K on NM_015318.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 299/654 reads (46%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.585); catalogued as rs993334421, COSV100150146; called by muse, mutect2, varscan2
- ARL10 | c.346C>T p.R116C | Missense Mutation (SNP) | VAF 206/430 reads (48%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.981); catalogued as COSV53798213; called by muse, mutect2, varscan2
- ARL6 | c.154G>T p.G52* | Nonsense Mutation (SNP) | VAF 105/246 reads (43%) | catalogued as COSV100256607; called by muse, mutect2, varscan2
- ARNT | c.1783del p.R595Gfs*11 | Frame Shift Del (DEL) | VAF 123/304 reads (40%) | catalogued as COSV62230627; called by mutect2, pindel, varscan2
- ASAH2 | c.1768C>T p.R590* | Nonsense Mutation (SNP) | VAF 154/322 reads (48%) | catalogued as rs1194660932, COSV61483494; called by muse, mutect2, varscan2
- ASS1 | c.490G>A p.A164T | Missense Mutation (SNP) | VAF 186/462 reads (40%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.546); catalogued as rs201445618; called by muse, mutect2, varscan2
- ASTN1 | c.484G>A p.A162T | Missense Mutation (SNP) | VAF 128/261 reads (49%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.994); catalogued as rs1364819044; called by muse, mutect2, varscan2
- ASTN2 | c.3989G>A p.R1330Q (on ENST00000313400 / NM_001365069.1; = p.R1279Q on NM_014010.5) | Missense Mutation (SNP) | VAF 202/346 reads (58%) | SIFT tolerated, low confidence (0.23); PolyPhen probably damaging (0.978); catalogued as rs367824366; called by muse, mutect2, varscan2
- ATG2B | c.1271C>A p.P424H | Missense Mutation (SNP) | VAF 177/348 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs746956149; called by muse, mutect2, varscan2
- ATG9B | c.2755C>T p.R919W | Missense Mutation (SNP) | VAF 141/292 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.059); catalogued as rs1312209539, COSV99871688; called by muse, varscan2
- ATG9B | c.2646C>T p.D882= | Splice Region (SNP) | VAF 170/334 reads (51%) | catalogued as rs545593603, COSV99872428; called by muse, varscan2
- ATP5MC2 | c.205G>A p.D69N | Missense Mutation (SNP) | VAF 189/418 reads (45%) | SIFT tolerated (0.07); PolyPhen benign (0.017); catalogued as rs781062050, COSV58601745; called by muse, mutect2, varscan2
- ATP8B1 | c.3695C>T p.S1232L | Missense Mutation (SNP) | VAF 276/546 reads (51%) | SIFT tolerated (0.32); PolyPhen benign (0.01); catalogued as rs778749552, COSV52173063; called by muse, varscan2
- ATP9B | c.1946C>T p.T649M | Missense Mutation (SNP) | VAF 38/360 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as rs760709646; called by muse, mutect2
- ATXN3L | c.585del p.K195Nfs*2 | Frame Shift Del (DEL) | VAF 174/251 reads (69%) | catalogued as rs1411781059; called by mutect2, pindel, varscan2
- AVPI1 | c.139G>A p.G47R | Missense Mutation (SNP) | VAF 289/602 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs773089599; called by muse, mutect2, varscan2
- AXIN1 | c.187C>T p.R63C | Missense Mutation (SNP) | VAF 246/511 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs145608130; called by muse, mutect2, varscan2
- AXL | c.874del p.H292Ifs*5 | Frame Shift Del (DEL) | VAF 310/632 reads (49%) | catalogued as rs778012871; called by mutect2, varscan2
- B3GLCT | c.1258G>A p.D420N | Missense Mutation (SNP) | VAF 183/393 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs769182025; called by muse, mutect2, varscan2
- B3GNT9 | c.868G>A p.G290S | Missense Mutation (SNP) | VAF 266/537 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1329819842, COSV54628915; called by muse, mutect2, varscan2
- BAG5 | c.1174G>A p.D392N | Missense Mutation (SNP) | VAF 181/363 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs758744586, COSV99915014; called by muse, mutect2, varscan2
- BEND7 | c.761G>A p.R254H | Missense Mutation (SNP) | VAF 187/387 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as rs1184445078; called by muse, varscan2
- BEST2 | c.1066C>T p.R356W | Missense Mutation (SNP) | VAF 205/436 reads (47%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.677); catalogued as rs757587843, COSV50363408; called by muse, mutect2, varscan2
- BHLHA15 | c.193G>A p.G65R | Missense Mutation (SNP) | VAF 333/675 reads (49%) | SIFT tolerated (0.11); PolyPhen benign (0.153); catalogued as rs750704418; called by muse, mutect2, varscan2
- BICD1 | c.1078G>A p.A360T | Missense Mutation (SNP) | VAF 171/355 reads (48%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.999); catalogued as COSV99863162; called by muse, mutect2, varscan2
- BICRA | c.4420C>T p.R1474W | Missense Mutation (SNP) | VAF 403/866 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs1215558782, COSV67604756; called by muse, mutect2, varscan2
- BIRC6 | c.9685C>T p.L3229F | Missense Mutation (SNP) | VAF 94/209 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.733); catalogued as rs1216100664; called by muse, mutect2, varscan2
- BIVM-ERCC5 | c.2734G>A p.V912I | Missense Mutation (SNP) | VAF 201/426 reads (47%) | SIFT tolerated, low confidence (0.56); PolyPhen benign (0.023); catalogued as rs140135562; called by muse, mutect2, varscan2
- BLNK | c.1174C>T p.R392* | Nonsense Mutation (SNP) | VAF 114/257 reads (44%) | catalogued as rs200501515; called by muse, mutect2, varscan2
- BMERB1 | c.413G>A p.R138Q | Missense Mutation (SNP) | VAF 188/367 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1208487544, COSV100252561; called by muse, mutect2, varscan2
- BMPR2 | c.1748del p.N583Tfs*44 | Frame Shift Del (DEL) | VAF 191/455 reads (42%) | catalogued as rs772920507, COSV65808737; called by mutect2, pindel, varscan2
- BNC1 | c.2912G>T p.R971L | Missense Mutation (SNP) | VAF 193/468 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV61757595; called by muse, mutect2, varscan2
- BRAP | c.671G>A p.R224H | Missense Mutation (SNP) | VAF 211/442 reads (48%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.987); catalogued as rs770298646, COSV59537780; called by muse, mutect2, varscan2
- BRAT1 | c.1304C>T p.T435M | Missense Mutation (SNP) | VAF 197/415 reads (47%) | SIFT tolerated (0.06); PolyPhen benign (0.009); catalogued as rs745563920, COSV61397659; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BRD1 | c.1204G>A p.G402R | Missense Mutation (SNP) | VAF 202/417 reads (48%) | SIFT tolerated (0.06); PolyPhen benign (0.124); catalogued as rs1254272998, COSV99350570; called by muse, mutect2, varscan2
- BRD3 | c.1634C>T p.T545M | Missense Mutation (SNP) | VAF 127/343 reads (37%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.638); catalogued as rs774040378, COSV57702822; called by muse, mutect2, varscan2
- BRPF3 | c.2269G>A p.A757T | Missense Mutation (SNP) | VAF 285/570 reads (50%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs1442029620; called by muse, mutect2, varscan2
- BRSK1 | c.1669C>T p.R557C | Missense Mutation (SNP) | VAF 314/689 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.548); catalogued as rs755357977; called by muse, mutect2, varscan2
- BRSK1 | c.2036G>A p.R679Q | Missense Mutation (SNP) | VAF 229/507 reads (45%) | SIFT tolerated (0.13); PolyPhen benign (0.028); catalogued as rs200690719; called by muse, mutect2, varscan2
- BSCL2 | c.842G>A p.R281Q | Missense Mutation (SNP) | VAF 151/308 reads (49%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs202072835; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BSN | c.3359G>A p.R1120H | Missense Mutation (SNP) | VAF 258/511 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs771863939; called by muse, mutect2, varscan2
- BTN1A1 | c.166G>A p.A56T | Missense Mutation (SNP) | VAF 54/584 reads (9%) | SIFT tolerated (0.27); PolyPhen benign (0.01); catalogued as COSV55068501; called by muse, mutect2
- BTNL9 | c.322A>G p.K108E | Missense Mutation (SNP) | VAF 218/417 reads (52%) | SIFT deleterious (0.04); PolyPhen benign (0.155); catalogued as rs781133085; called by muse, mutect2, varscan2
- C11orf95 | c.1397C>T p.T466M | Missense Mutation (SNP) | VAF 347/690 reads (50%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.975); catalogued as rs1192269990, COSV58032727; called by muse, varscan2
- C18orf54 | c.1067G>A p.R356H | Missense Mutation (SNP) | VAF 68/168 reads (40%) | SIFT tolerated (0.28); PolyPhen benign (0.157); catalogued as rs146934571, COSV100266395; called by muse, varscan2
- C2CD5 | c.407G>A p.R136Q | Missense Mutation (SNP) | VAF 124/240 reads (52%) | SIFT tolerated (0.21); PolyPhen benign (0.006); catalogued as rs139822705; called by muse, mutect2, varscan2
- C5 | c.2503C>T p.R835* | Nonsense Mutation (SNP) | VAF 137/349 reads (39%) | catalogued as COSV56325970; called by muse, mutect2, varscan2
- C5orf46 | c.196C>T p.R66C | Missense Mutation (SNP) | VAF 138/256 reads (54%) | SIFT tolerated (0.1); PolyPhen benign (0.037); catalogued as rs375956579; called by muse, mutect2, varscan2
- C6orf132 | c.1045G>A p.A349T | Missense Mutation (SNP) | VAF 294/603 reads (49%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.952); catalogued as rs1275712359; called by muse, mutect2, varscan2
- C6orf132 | c.920del p.P307Qfs*210 | Frame Shift Del (DEL) | VAF 272/649 reads (42%) | catalogued as COSV59375430; called by mutect2, pindel, varscan2
- CACNA1A | c.985G>A p.D329N | Missense Mutation (SNP) | VAF 114/238 reads (48%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.56); catalogued as rs1353041373; called by muse, mutect2, varscan2
- CACNA1B | c.4703G>A p.R1568H | Missense Mutation (SNP) | VAF 147/377 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV99501175; called by muse, mutect2, varscan2
- CACNA1I | c.2476G>A p.V826I | Missense Mutation (SNP) | VAF 166/326 reads (51%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.5); catalogued as rs1278074840, COSV60802941; called by muse, mutect2, varscan2
- CACNA1S | c.2794G>A p.V932M | Missense Mutation (SNP) | VAF 180/392 reads (46%) | SIFT tolerated (0.7); PolyPhen probably damaging (0.992); catalogued as rs373701906; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CACNA2D2 | c.1259C>T p.T420M | Missense Mutation (SNP) | VAF 155/316 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs781210506, COSV99818083; called by muse, mutect2, varscan2
- CALD1 | c.124C>T p.R42C | Missense Mutation (SNP) | VAF 187/402 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62646346; called by muse, mutect2, varscan2
- CALHM3 | c.883C>T p.R295W | Missense Mutation (SNP) | VAF 296/617 reads (48%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as rs867022038; called by muse, mutect2, varscan2
- CAMKK2 | c.1639C>A p.P547T | Missense Mutation (SNP) | VAF 262/509 reads (51%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.011); catalogued as rs1310112012; called by muse, varscan2
- CAMTA1 | c.772C>T p.R258W | Missense Mutation (SNP) | VAF 214/480 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.72); catalogued as rs1470142432, COSV57909520; called by muse, mutect2, varscan2
- CAMTA1 | c.968G>A p.R323H | Missense Mutation (SNP) | VAF 166/353 reads (47%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.991); catalogued as rs1181886794; called by muse, mutect2, varscan2
- CAPN10 | c.416G>A p.R139H | Missense Mutation (SNP) | VAF 189/410 reads (46%) | SIFT tolerated (0.34); PolyPhen benign (0.26); catalogued as rs770374333; called by muse, mutect2, varscan2
- CAPN10 | c.1373G>A p.R458H | Missense Mutation (SNP) | VAF 270/558 reads (48%) | SIFT tolerated (0.81); PolyPhen benign (0.059); catalogued as rs752063033; called by muse, mutect2, varscan2
- CARD11 | c.1663del p.R555Gfs*45 | Frame Shift Del (DEL) | VAF 137/382 reads (36%) | catalogued as rs762770988, COSV62756627; called by pindel, varscan2
- CARD6 | c.2681C>A p.P894H | Missense Mutation (SNP) | VAF 208/444 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.635); catalogued as COSV99620956; called by mutect2, varscan2
- CASKIN2 | c.1390C>T p.R464C | Missense Mutation (SNP) | VAF 186/370 reads (50%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as rs371781299; called by muse, varscan2
- CASP8 | c.698G>A p.R233Q (on ENST00000432109 / NM_033355.3; = p.R250Q on NM_001228.4) | Missense Mutation (SNP) | VAF 121/293 reads (41%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.787); catalogued as rs771150445, COSV51844924; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CASZ1 | c.1207G>A p.V403M | Missense Mutation (SNP) | VAF 272/545 reads (50%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.006); catalogued as rs530151570, COSV59740183; called by muse, mutect2, varscan2
- CASZ1 | c.704G>A p.R235Q | Missense Mutation (SNP) | VAF 222/425 reads (52%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); catalogued as rs146887532; called by muse, mutect2, varscan2
- CCDC102B | c.1259dup p.N420Kfs*13 | Frame Shift Ins (INS) | VAF 64/140 reads (46%) | catalogued as rs562973346; called by mutect2, varscan2
- CCDC105 | c.805C>T p.R269* | Nonsense Mutation (SNP) | VAF 230/504 reads (46%) | catalogued as rs372493151; called by muse, mutect2, varscan2
- CCDC110 | c.2017G>A p.E673K | Missense Mutation (SNP) | VAF 128/321 reads (40%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as rs546423737, COSV56873334; called by muse, mutect2
- CCDC113 | c.371G>A p.R124H | Missense Mutation (SNP) | VAF 121/282 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.869); catalogued as rs147141699; called by muse, mutect2, varscan2
- CCDC120 | c.1363C>T p.R455C | Missense Mutation (SNP) | VAF 372/372 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs782072841, COSV64480869; called by muse, mutect2, varscan2
- CCDC136 | c.304C>G p.Q102E | Missense Mutation (SNP) | VAF 223/460 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.696); catalogued as rs1038089391; called by muse, mutect2, varscan2
- CCDC15 | c.547C>T p.R183W | Missense Mutation (SNP) | VAF 105/195 reads (54%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); catalogued as rs760911695, COSV100776989, COSV61084753; called by muse, mutect2, varscan2
- CCDC166 | c.676C>T p.R226C | Missense Mutation (SNP) | VAF 436/847 reads (51%) | SIFT deleterious (0); PolyPhen benign (0.053); catalogued as COSV101545877; called by muse, mutect2, varscan2
- CCDC170 | c.1448C>T p.A483V | Missense Mutation (SNP) | VAF 160/326 reads (49%) | SIFT tolerated (0.15); PolyPhen benign (0.122); catalogued as rs200841666, COSV53339624; called by muse, mutect2
- CCDC180 | c.2196G>T p.E732D | Missense Mutation (SNP) | VAF 261/517 reads (50%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.537); catalogued as rs12353275; called by muse, mutect2, varscan2
- CCDC180 | c.4614del p.K1539Nfs*17 | Frame Shift Del (DEL) | VAF 126/331 reads (38%) | catalogued as rs1423532083; called by mutect2, pindel, varscan2
- CCDC181 | c.190C>T p.R64W | Missense Mutation (SNP) | VAF 167/367 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.409); catalogued as rs187334513; called by muse, mutect2, varscan2
- CCDC34 | c.731del p.N244Mfs*28 | Frame Shift Del (DEL) | VAF 104/260 reads (40%) | catalogued as rs773019149; called by mutect2, varscan2
- CCDC73 | c.1341del p.E448Kfs*5 | Frame Shift Del (DEL) | VAF 54/147 reads (37%) | catalogued as rs747079826; called by mutect2, varscan2
- CCDC81 | c.1400C>T p.A467V (on ENST00000445632 / NM_001156474.2; = p.A377V on NM_021827.4) | Missense Mutation (SNP) | VAF 121/267 reads (45%) | SIFT deleterious (0.03); PolyPhen benign (0.196); catalogued as rs771099705; called by muse, mutect2, varscan2
- CCHCR1 | c.1463G>A p.R488H | Missense Mutation (SNP) | VAF 285/623 reads (46%) | SIFT tolerated (0.14); PolyPhen benign (0.019); catalogued as rs1165145831; called by muse, mutect2, varscan2
- CCHCR1 | c.1153C>T p.R385* | Nonsense Mutation (SNP) | VAF 258/568 reads (45%) | catalogued as rs767157475, COSV100885732; called by muse, mutect2, varscan2
- CCNJL | c.115C>T p.R39C | Missense Mutation (SNP) | VAF 200/409 reads (49%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.995); catalogued as rs748396775; called by muse, mutect2, varscan2
- CCR6 | c.890C>T p.T297M | Missense Mutation (SNP) | VAF 175/345 reads (51%) | SIFT deleterious (0.01); PolyPhen benign (0.166); catalogued as rs774906837; called by muse, mutect2, varscan2
- CCR9 | c.430A>G p.R144G (on ENST00000357632 / NM_031200.3; = p.R132G on NM_006641.4) | Missense Mutation (SNP) | VAF 223/422 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs748863151; called by muse, mutect2, varscan2
- CD151 | c.271C>T p.R91C | Missense Mutation (SNP) | VAF 152/307 reads (50%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.86); catalogued as rs1019424026; called by muse, mutect2, varscan2
- CD247 | c.274C>T p.R92W | Missense Mutation (SNP) | VAF 187/345 reads (54%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.446); catalogued as rs144963570; called by muse, mutect2, varscan2
- CD40 | c.382G>A p.G128S | Missense Mutation (SNP) | VAF 144/308 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs754006524, COSV100953780; called by muse, mutect2, varscan2
- CD5L | c.919C>T p.R307C | Missense Mutation (SNP) | VAF 214/437 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); catalogued as rs74121552, COSV63823026; called by muse, mutect2, varscan2
- CDC123 | c.862C>T p.R288C | Missense Mutation (SNP) | VAF 138/291 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs752328200, COSV55395725; called by muse, mutect2, varscan2
- CDC16 | c.217C>T p.R73C | Missense Mutation (SNP) | VAF 132/275 reads (48%) | SIFT tolerated (0.06); PolyPhen benign (0.043); catalogued as COSV52958720; called by muse, mutect2, varscan2
- CDC42BPB | c.1846C>T p.R616W | Missense Mutation (SNP) | VAF 193/408 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs780626139; called by muse, varscan2
- CDH10 | c.385G>A p.A129T | Missense Mutation (SNP) | VAF 204/408 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs760804087, COSV52572298, COSV52585105; called by muse, mutect2, varscan2
- CDH19 | c.1841del p.L614* | Frame Shift Del (DEL) | VAF 62/173 reads (36%) | catalogued as rs1568168060; called by mutect2, pindel, varscan2
- CDH2 | c.580C>T p.R194W | Missense Mutation (SNP) | VAF 13/310 reads (4%) | SIFT tolerated (0.18); PolyPhen probably damaging (1); catalogued as rs1228174771; called by muse, mutect2
- CDH9 | c.1760G>A p.R587H | Missense Mutation (SNP) | VAF 232/462 reads (50%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.983); catalogued as rs763497540, COSV50254621, COSV50464003; called by muse, mutect2, varscan2
- CDHR2 | c.466G>A p.A156T | Missense Mutation (SNP) | VAF 223/494 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.079); catalogued as rs745929407; called by muse, mutect2
- CDK12 | c.4067G>A p.R1356Q (on ENST00000447079 / NM_016507.4; = p.R1347Q on NM_015083.3) | Missense Mutation (SNP) | VAF 228/464 reads (49%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.273); catalogued as rs761089485, COSV71001791; called by muse, mutect2, varscan2
- CDK5RAP2 | c.4223G>A p.R1408H | Missense Mutation (SNP) | VAF 117/285 reads (41%) | SIFT tolerated (0.08); PolyPhen benign (0.028); catalogued as rs1014026370; called by muse, mutect2, varscan2
- CDK6 | c.658C>T p.R220C | Missense Mutation (SNP) | VAF 107/214 reads (50%) | SIFT tolerated (0.15); PolyPhen benign (0.022); catalogued as rs373488172, COSV56008836; called by muse, mutect2, varscan2
- CDKN3 | c.130G>A p.G44S | Missense Mutation (SNP) | VAF 147/299 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1286825216; called by muse, mutect2, varscan2
- CDRT1 | c.1861G>A p.V621M | Missense Mutation (SNP) | VAF 129/299 reads (43%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.791); catalogued as rs369935359; called by muse, mutect2, varscan2
- CEACAM16 | c.1123G>A p.A375T | Missense Mutation (SNP) | VAF 267/581 reads (46%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs777496967, COSV101312772; called by muse, mutect2, varscan2
- CELF2 | c.1127C>T p.T376M (on ENST00000416382 / NM_001025077.3; = p.T389M on NM_006561.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 216/413 reads (52%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.776); catalogued as COSV100258199; called by muse, mutect2, varscan2
- CELSR2 | c.5410G>A p.A1804T | Missense Mutation (SNP) | VAF 234/464 reads (50%) | SIFT tolerated (0.56); PolyPhen benign (0.001); catalogued as rs770840359; called by muse, mutect2, varscan2
- CEMIP2 | c.557C>T p.A186V | Missense Mutation (SNP) | VAF 211/408 reads (52%) | SIFT tolerated (0.11); PolyPhen benign (0.182); catalogued as rs778331613, COSV100987406; called by muse, mutect2, varscan2
- CENPF | c.8509G>A p.D2837N | Missense Mutation (SNP) | VAF 103/204 reads (50%) | SIFT deleterious (0.02); PolyPhen benign (0.071); catalogued as rs138734779; called by muse, mutect2, varscan2
- CENPQ | c.125del p.N42Ifs*5 | Frame Shift Del (DEL) | VAF 86/188 reads (46%) | catalogued as rs756590976; called by mutect2, varscan2
- CEP170B | c.723del p.E242Rfs*41 (on ENST00000453495; = p.E171Rfs*41 on NM_015005.3) | Frame Shift Del (DEL) | VAF 355/858 reads (41%) | catalogued as COSV69024902; called by mutect2, pindel, varscan2
- CEP192 | c.2362del p.T788Qfs*40 | Frame Shift Del (DEL) | VAF 98/277 reads (35%) | catalogued as COSV58068098; called by mutect2, pindel, varscan2
- CEP192 | c.6476_6477del p.S2159Cfs*7 | Frame Shift Del (DEL) | VAF 130/353 reads (37%) | catalogued as rs1433048204; called by pindel, varscan2
- CEP350 | c.6232del p.R2078Gfs*6 | Frame Shift Del (DEL) | VAF 124/258 reads (48%) | catalogued as rs759430139; called by mutect2, varscan2
- CEP95 | c.1940G>A p.R647H | Missense Mutation (SNP) | VAF 99/227 reads (44%) | SIFT tolerated (0.75); PolyPhen benign (0); catalogued as rs782398984; called by muse, varscan2
- CFAP100 | c.1104del p.T369Rfs*36 | Frame Shift Del (DEL) | VAF 129/311 reads (41%) | catalogued as rs747835123, COSV61504174; called by mutect2, pindel, varscan2
- CFAP46 | c.7358C>T p.A2453V | Missense Mutation (SNP) | VAF 148/325 reads (46%) | SIFT tolerated (0.36); PolyPhen benign (0.006); catalogued as rs768215654; called by muse, mutect2, varscan2
- CFAP61 | c.2402G>A p.R801Q | Missense Mutation (SNP) | VAF 154/326 reads (47%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as rs567725378; called by muse, varscan2
- CFAP65 | c.3467G>A p.R1156Q | Missense Mutation (SNP) | VAF 32/325 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.457); catalogued as rs555153852; called by muse, mutect2, varscan2
- CGB2 | c.334C>T p.R112C | Missense Mutation (SNP) | VAF 66/380 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.044); catalogued as rs1429495580; called by muse, mutect2, varscan2
- CGB3 | c.340C>T p.R114C | Missense Mutation (SNP) | VAF 165/600 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.173); catalogued as rs1462326318; called by muse, mutect2, varscan2
- CHD1 | c.3960del p.E1321Kfs*22 | Frame Shift Del (DEL) | VAF 107/279 reads (38%) | catalogued as rs1561489348; called by mutect2, pindel, varscan2
- CHD2 | c.44T>C p.L15P | Missense Mutation (SNP) | VAF 227/518 reads (44%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0); catalogued as rs1060503522; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CHD2 | c.341G>A p.R114Q | Missense Mutation (SNP) | VAF 124/249 reads (50%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.978); catalogued as COSV100560575; called by muse, mutect2, varscan2
- CHD4 | c.3244C>T p.R1082C (on ENST00000357008 / NM_001363606.2; = p.R1095C on NM_001273.5) | Missense Mutation (SNP) | VAF 218/484 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100538432; called by muse, mutect2, varscan2
- CHD7 | c.1244C>T p.P415L | Missense Mutation (SNP) | VAF 173/410 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.585); catalogued as rs765180149; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CHD7 | c.6080G>T p.R2027L | Missense Mutation (SNP) | VAF 111/272 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.382); catalogued as COSV71112607; called by mutect2, varscan2
- CHFR | c.833G>A p.R278H (on ENST00000432561 / NM_001161345.1; = p.R237H on NM_018223.2) | Missense Mutation (SNP) | VAF 174/386 reads (45%) | SIFT tolerated (0.29); PolyPhen benign (0.075); catalogued as rs375174098; called by muse, mutect2, varscan2
- CHFR | c.478C>T p.R160W | Missense Mutation (SNP) | VAF 226/429 reads (53%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as rs746187833; called by muse, mutect2, varscan2
- CHID1 | c.1171G>A p.D391N | Missense Mutation (SNP) | VAF 231/473 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.682); catalogued as rs777138598; called by muse, mutect2, varscan2
- CHRNA7 | c.1406G>A p.R469H | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1401153406, COSV100181202; called by mutect2, varscan2
- CHRNB2 | c.659C>T p.T220M | Missense Mutation (SNP) | VAF 216/418 reads (52%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.969); catalogued as rs796052326, COSV100872517; ClinVar: uncertain significance; called by muse, varscan2
- CHST1 | c.1052G>A p.R351Q | Missense Mutation (SNP) | VAF 322/646 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57322988; called by muse, mutect2, varscan2
- CHST8 | c.272C>T p.A91V | Missense Mutation (SNP) | VAF 332/641 reads (52%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as rs759507836; called by muse, mutect2, varscan2
- CHSY3 | c.1048C>T p.R350C | Missense Mutation (SNP) | VAF 29/380 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs777729488, COSV59272015; called by muse, mutect2
- CIAO1 | c.304G>A p.E102K | Missense Mutation (SNP) | VAF 126/272 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.554); catalogued as rs772533972; called by muse, mutect2, varscan2
- CIC | c.662G>A p.R221H | Missense Mutation (SNP) | VAF 20/698 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV50547229; called by muse, mutect2
- CIP2A | c.2422del p.T808Qfs*29 | Frame Shift Del (DEL) | VAF 71/180 reads (39%) | catalogued as COSV99843074; called by mutect2, pindel, varscan2
- CISD2 | c.239C>T p.P80L | Missense Mutation (SNP) | VAF 102/245 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.89); catalogued as rs868634687; called by muse, mutect2, varscan2
- CKM | c.1096_1098del p.K366del | In Frame Del (DEL) | VAF 220/427 reads (52%) | catalogued as rs780083622; called by pindel, varscan2
- CLASP1 | c.1387C>T p.R463C | Missense Mutation (SNP) | VAF 114/233 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1472982745, COSV55336545; called by muse, mutect2, varscan2
- CLASRP | c.584C>T p.S195L | Missense Mutation (SNP) | VAF 186/413 reads (45%) | SIFT tolerated (0.08); catalogued as rs780663630; called by muse, mutect2
- CLCN7 | c.1918C>T p.R640W | Missense Mutation (SNP) | VAF 155/291 reads (53%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.956); catalogued as rs1400598641, COSV99246906; called by muse, mutect2, varscan2
- CLIP2 | c.2954G>A p.R985Q | Missense Mutation (SNP) | VAF 250/541 reads (46%) | SIFT tolerated (0.18); PolyPhen benign (0.179); catalogued as rs782545372, COSV56281635; called by muse, mutect2, varscan2
- CLIP3 | c.640G>A p.A214T | Missense Mutation (SNP) | VAF 159/370 reads (43%) | SIFT tolerated (0.1); PolyPhen benign (0.267); catalogued as COSV62112754; called by muse, mutect2, varscan2
- CLK3 | c.712C>T p.R238C (on ENST00000395066 / NM_001130028.1; = p.R90C on NM_003992.4) | Missense Mutation (SNP) | VAF 238/525 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.328); catalogued as rs767369515; called by muse, mutect2, varscan2
- CLOCK | c.368del p.L123* | Frame Shift Del (DEL) | VAF 127/242 reads (52%) | catalogued as rs369752219; called by mutect2, varscan2
- CLPTM1L | c.308C>T p.T103M | Missense Mutation (SNP) | VAF 238/433 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1019362368; called by muse, mutect2, varscan2
- CLSTN1 | c.157G>A p.V53M | Missense Mutation (SNP) | VAF 128/276 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1363487449; called by muse, mutect2, varscan2
- CMTR1 | c.430C>T p.R144* | Nonsense Mutation (SNP) | VAF 119/228 reads (52%) | catalogued as rs747046392; called by muse, mutect2, varscan2
- CMTR1 | c.1172C>T p.A391V | Missense Mutation (SNP) | VAF 154/309 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as rs759199278; called by muse, mutect2, varscan2
- CNBD1 | c.1180G>T p.G394W | Missense Mutation (SNP) | VAF 114/187 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV73074582; called by muse, mutect2, varscan2
- CNOT6L | c.538C>T p.R180* (on ENST00000504123 / NM_001286790.2; = p.R175* on NM_144571.3 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 158/328 reads (48%) | catalogued as COSV53701253; called by muse, mutect2, varscan2
- CNR1 | c.1358C>T p.T453M | Missense Mutation (SNP) | VAF 178/385 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.818); catalogued as COSV62986486; called by muse, mutect2, varscan2
- COL11A2 | c.4482G>A p.P1494= (on ENST00000341947 / NM_080680.3; = p.P1387= on NM_080679.2) | Splice Region (SNP) | VAF 229/473 reads (48%) | catalogued as rs142586242, COSV59503302; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COL4A1 | c.3307G>A p.G1103R | Missense Mutation (SNP) | VAF 192/401 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM128683, COSV65422174; called by muse, mutect2, varscan2
- COL5A1 | c.4121C>T p.T1374M | Missense Mutation (SNP) | VAF 156/332 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.642); catalogued as rs151115748; ClinVar: uncertain significance; called by muse, varscan2
- COL5A1 | c.4909C>T p.R1637C | Missense Mutation (SNP) | VAF 215/394 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs753433375, COSV100880383, COSV65669482; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COL6A1 | c.1378G>A p.V460I | Missense Mutation (SNP) | VAF 176/411 reads (43%) | SIFT tolerated (0.25); PolyPhen benign (0.003); catalogued as rs375452881; called by muse, mutect2, varscan2
- COL6A6 | c.4504C>T p.R1502C | Missense Mutation (SNP) | VAF 131/288 reads (45%) | SIFT tolerated (0.19); PolyPhen benign (0.353); catalogued as rs764994836, COSV62023950; called by muse, mutect2, varscan2
- COL9A1 | c.848del p.P283Lfs*45 | Frame Shift Del (DEL) | VAF 145/402 reads (36%) | catalogued as rs941174282; called by pindel, varscan2
- COPA | c.877C>T p.R293C | Missense Mutation (SNP) | VAF 157/342 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1253097566, COSV54107149; called by muse, mutect2, varscan2
- COPG1 | c.376C>T p.R126* | Nonsense Mutation (SNP) | VAF 166/356 reads (47%) | catalogued as rs775727605, COSV59116628; called by muse, mutect2, varscan2
- COPRS | c.90del p.S31Afs*25 | Frame Shift Del (DEL) | VAF 181/435 reads (42%) | catalogued as rs1567771049; called by mutect2, pindel, varscan2
- CORIN | c.1208A>G p.E403G | Missense Mutation (SNP) | VAF 180/392 reads (46%) | SIFT tolerated (0.23); PolyPhen benign (0.122); catalogued as COSV99904277; called by muse, mutect2
- CPNE4 | c.274C>T p.R92W | Missense Mutation (SNP) | VAF 118/381 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as rs1355312776, COSV101456545; called by muse, mutect2, varscan2
- CPNE5 | c.1757C>T p.A586V | Missense Mutation (SNP) | VAF 232/480 reads (48%) | SIFT tolerated (0.14); PolyPhen benign (0.005); catalogued as rs778477100; called by muse, mutect2, varscan2
- CPNE8 | c.285del p.F95Lfs*41 | Frame Shift Del (DEL) | VAF 78/199 reads (39%) | catalogued as COSV58849117; called by mutect2, pindel, varscan2
- CPT1A | c.2141C>T p.P714L | Missense Mutation (SNP) | VAF 141/291 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs139057953; called by muse, mutect2, varscan2
- CR2 | c.2503A>G p.T835A | Missense Mutation (SNP) | VAF 147/301 reads (49%) | SIFT tolerated (0.12); PolyPhen benign (0.266); catalogued as rs1367099391; called by muse, mutect2, varscan2
- CRAT | c.1868G>A p.R623Q | Missense Mutation (SNP) | VAF 175/326 reads (54%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as rs760770816, COSV100540034; called by muse, mutect2, varscan2
- CRB1 | c.1750G>A p.D584N | Missense Mutation (SNP) | VAF 166/371 reads (45%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.793); catalogued as CM040711, COSV66329127, COSV66331096; called by muse, mutect2, varscan2
- CROT | c.1514G>A p.R505H | Missense Mutation (SNP) | VAF 21/289 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs778562643; called by muse, mutect2
- CRTAM | c.98C>T p.T33M | Missense Mutation (SNP) | VAF 96/349 reads (28%) | SIFT tolerated (0.17); PolyPhen benign (0.115); catalogued as rs775161741, COSV57066614; called by muse, mutect2, varscan2
- CRTC2 | c.1748G>A p.G583E | Missense Mutation (SNP) | VAF 256/532 reads (48%) | SIFT tolerated (0.17); PolyPhen benign (0.01); catalogued as rs1433609577; called by muse, mutect2, varscan2
- CSF1R | c.2257C>T p.R753W | Missense Mutation (SNP) | VAF 190/399 reads (48%) | SIFT tolerated (0.21); PolyPhen benign (0.005); catalogued as rs372068592; called by muse, mutect2, varscan2
- CSF3R | c.1243G>A p.G415R | Missense Mutation (SNP) | VAF 166/345 reads (48%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs779227407, COSV58966490; called by muse, mutect2, varscan2
- CSMD2 | c.3485G>A p.R1162H | Missense Mutation (SNP) | VAF 91/346 reads (26%) | SIFT tolerated (0.26); PolyPhen benign (0.382); catalogued as rs201989989; called by muse, mutect2, varscan2
- CSMD2 | c.2743C>T p.R915W | Missense Mutation (SNP) | VAF 149/298 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs759408814; called by muse, mutect2, varscan2
- CSMD2 | c.1703C>T p.S568L | Missense Mutation (SNP) | VAF 109/238 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV53882610; called by muse, mutect2, varscan2
- CSNK1E | c.1052C>T p.T351M | Missense Mutation (SNP) | VAF 280/541 reads (52%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.614); catalogued as rs759550035; called by muse, varscan2
- CSPG4 | c.6739C>T p.R2247* | Nonsense Mutation (SNP) | VAF 219/401 reads (55%) | catalogued as rs777249049, COSV57889753; called by muse, mutect2, varscan2
- CST6 | c.4G>A p.A2T | Missense Mutation (SNP) | VAF 261/554 reads (47%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as rs1411186911; called by muse, mutect2, varscan2
- CTNNA2 | c.347C>T p.S116L | Missense Mutation (SNP) | VAF 183/395 reads (46%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.83); catalogued as rs752704214, COSV63547968; called by muse, mutect2, varscan2
- CTNNAL1 | c.1696G>A p.A566T | Missense Mutation (SNP) | VAF 177/355 reads (50%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.961); catalogued as rs1250786842; called by muse, mutect2, varscan2
- CTNNBL1 | c.172del p.R58Gfs*25 | Frame Shift Del (DEL) | VAF 168/440 reads (38%) | catalogued as rs761516328; called by mutect2, pindel, varscan2
- CTNNBL1 | c.1246C>T p.R416W | Missense Mutation (SNP) | VAF 155/349 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs757144734; called by muse, mutect2, varscan2
- CTNND1 | c.1061G>A p.R354H | Missense Mutation (SNP) | VAF 165/321 reads (51%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.607); catalogued as rs754613241, COSV62382631; called by muse, mutect2, varscan2
- CTSV | c.685G>A p.A229T | Missense Mutation (SNP) | VAF 203/498 reads (41%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as rs372363372; called by muse, mutect2, varscan2
- CTTN | c.1609C>T p.R537W | Missense Mutation (SNP) | VAF 166/309 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs267603163; called by muse, varscan2
- CWC22 | c.1028G>A p.R343Q | Missense Mutation (SNP) | VAF 174/335 reads (52%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs373594028; called by muse, mutect2, varscan2
- CWC27 | c.242C>T p.A81V | Missense Mutation (SNP) | VAF 118/271 reads (44%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs765721927; called by muse, mutect2, varscan2
- CYB5R1 | c.587G>A p.R196Q | Missense Mutation (SNP) | VAF 189/409 reads (46%) | SIFT tolerated (0.07); PolyPhen benign (0.022); catalogued as rs755233575, COSV100924852; called by muse, mutect2, varscan2
- CYB5R4 | c.741del p.E248Rfs*12 | Frame Shift Del (DEL) | VAF 190/193 reads (98%) | catalogued as rs745836350; called by mutect2, varscan2
- CYFIP1 | c.3073G>A p.A1025T | Missense Mutation (SNP) | VAF 161/311 reads (52%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.937); catalogued as rs769699388; called by muse, mutect2, varscan2
- CYHR1 | c.563C>T p.A188V | Missense Mutation (SNP) | VAF 184/361 reads (51%) | SIFT tolerated (0.35); PolyPhen benign (0.113); catalogued as COSV71324651; called by muse, mutect2, varscan2
- CYP1B1 | c.565G>A p.A189T | Missense Mutation (SNP) | VAF 354/717 reads (49%) | SIFT tolerated (0.37); PolyPhen benign (0.007); catalogued as CM066030; called by muse, mutect2, varscan2
- CYP46A1 | c.1480G>A p.A494T | Missense Mutation (SNP) | VAF 237/551 reads (43%) | SIFT tolerated, low confidence (0.2); PolyPhen probably damaging (0.978); catalogued as rs756141971; called by muse, mutect2, varscan2
- CYTH2 | c.960G>A p.P320= (on ENST00000427476; = p.P319= on NM_004228.7) | Splice Region (SNP) | VAF 140/304 reads (46%) | catalogued as rs766860687, COSV57309254; called by muse, varscan2
- DAPK1 | c.1594G>A p.E532K | Missense Mutation (SNP) | VAF 112/287 reads (39%) | SIFT deleterious (0.03); PolyPhen benign (0.196); catalogued as rs370724837; called by muse, mutect2, varscan2
- DAZAP1 | c.743C>T p.P248L | Missense Mutation (SNP) | VAF 73/148 reads (49%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.982); catalogued as rs1053723670, COSV99245627; called by muse, mutect2, varscan2
- DBF4B | c.1706G>A p.R569Q | Missense Mutation (SNP) | VAF 253/490 reads (52%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs774163525; called by muse, mutect2, varscan2
- DCAF1 | c.3008C>T p.T1003M | Missense Mutation (SNP) | VAF 192/392 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); catalogued as rs782486639; called by muse, varscan2
- DCAF12L2 | c.1025G>A p.R342Q | Missense Mutation (SNP) | VAF 320/320 reads (100%) | SIFT tolerated (0.32); PolyPhen benign (0.006); catalogued as COSV63583920; called by muse, mutect2, varscan2
- DCAF5 | c.757C>T p.R253* | Nonsense Mutation (SNP) | VAF 216/446 reads (48%) | catalogued as COSV58458695; called by muse, mutect2, varscan2
- DCHS1 | c.7756G>A p.V2586M | Missense Mutation (SNP) | VAF 189/360 reads (53%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as rs747141130, COSV54996502; called by muse, mutect2, varscan2
- DCHS1 | c.5431C>T p.R1811W | Missense Mutation (SNP) | VAF 192/403 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs757316767, COSV55044575; called by muse, mutect2, varscan2
- DCXR | c.677G>A p.R226Q | Missense Mutation (SNP) | VAF 148/326 reads (45%) | SIFT tolerated (0.16); PolyPhen benign (0.026); catalogued as rs752090622; called by muse, varscan2
- DDN | c.1411dup p.R471Pfs*31 | Frame Shift Ins (INS) | VAF 242/616 reads (39%) | catalogued as rs773412144; called by mutect2, pindel, varscan2
- DDRGK1 | c.367C>T p.R123W | Missense Mutation (SNP) | VAF 175/321 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs753666292, COSV100621543; called by muse, varscan2
- DDX11 | c.880G>A p.E294K | Missense Mutation (SNP) | VAF 109/238 reads (46%) | SIFT tolerated (0.35); PolyPhen benign (0.031); catalogued as rs751955009, COSV99299994; called by muse, mutect2, varscan2
- DDX56 | c.98T>C p.I33T | Missense Mutation (SNP) | VAF 145/509 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV51836916; called by muse, mutect2, varscan2
- DDX60L | c.3338del p.L1113Cfs*38 | Frame Shift Del (DEL) | VAF 64/144 reads (44%) | catalogued as rs757771764; called by mutect2, varscan2
- DENND1A | c.1654C>T p.R552W | Missense Mutation (SNP) | VAF 267/649 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.232); catalogued as rs754417395; called by muse, mutect2, varscan2
- DENND4A | c.1693G>A p.A565T | Missense Mutation (SNP) | VAF 211/444 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1248901572; called by muse, mutect2, varscan2
- DESI2 | c.457G>A p.A153T | Missense Mutation (SNP) | VAF 178/379 reads (47%) | SIFT tolerated (0.42); PolyPhen benign (0.236); catalogued as rs373776959; called by muse, mutect2, varscan2
- DGKD | c.2027G>T p.S676I (on ENST00000264057 / NM_152879.3; = p.S632I on NM_003648.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 155/294 reads (53%) | SIFT deleterious (0.02); PolyPhen benign (0.001); catalogued as rs776171645, COSV51039375; called by muse, mutect2, varscan2
- DHX16 | c.575G>A p.R192Q | Missense Mutation (SNP) | VAF 275/553 reads (50%) | SIFT tolerated (0.05); PolyPhen benign (0.017); catalogued as rs1273530977, COSV64579712; called by muse, mutect2, varscan2
- DHX57 | c.2168G>A p.R723H | Missense Mutation (SNP) | VAF 88/227 reads (39%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.816); catalogued as rs772689230, COSV54892254; called by muse, mutect2, varscan2
- DHX9 | c.2306G>A p.R769Q | Missense Mutation (SNP) | VAF 155/348 reads (45%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.937); catalogued as COSV62359156; called by muse, mutect2, varscan2
- DIAPH3 | c.2581G>A p.G861R (on ENST00000400324 / NM_001042517.2; = p.G598R on NM_030932.3) | Missense Mutation (SNP) | VAF 118/269 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs368347883; called by muse, mutect2, varscan2
- DIP2C | c.508G>A p.G170S | Missense Mutation (SNP) | VAF 203/420 reads (48%) | SIFT tolerated (0.11); PolyPhen benign (0.02); catalogued as rs1485067164; called by muse, mutect2, varscan2
- DLEC1 | c.4387G>A p.V1463M | Missense Mutation (SNP) | VAF 109/228 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs199537711; called by muse, mutect2, varscan2
- DLG1 | c.1961G>A p.R654Q | Missense Mutation (SNP) | VAF 107/234 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.669); catalogued as rs560145346; called by muse, mutect2, varscan2
- DLGAP5 | c.1828G>A p.D610N | Missense Mutation (SNP) | VAF 165/314 reads (53%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs766110350; called by muse, mutect2, varscan2
- DMAC2 | c.568C>T p.R190W | Missense Mutation (SNP) | VAF 168/377 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs148395303; called by muse, mutect2, varscan2
- DMBX1 | c.224G>A p.R75H | Missense Mutation (SNP) | VAF 237/446 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100760721; called by muse, mutect2, varscan2
- DMD | c.7597G>A p.A2533T | Missense Mutation (SNP) | VAF 97/182 reads (53%) | SIFT tolerated (0.25); PolyPhen benign (0.284); catalogued as rs369583884, CD098168, COSV58896520; ClinVar: uncertain significance; called by muse, varscan2
- DNAH12 | c.6362G>A p.R2121H (on ENST00000351747; = p.R2140H on NM_001366028.2) | Missense Mutation (SNP) | VAF 203/401 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs969549110, COSV61054794; called by muse, mutect2, varscan2
- DNAH17 | c.8891C>T p.A2964V | Missense Mutation (SNP) | VAF 187/470 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs760238543, COSV67756311; called by muse, mutect2, varscan2
- DNAH3 | c.4760G>A p.R1587H | Missense Mutation (SNP) | VAF 147/266 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs765153588; called by muse, mutect2, varscan2
- DNAH5 | c.6268C>T p.R2090W | Missense Mutation (SNP) | VAF 118/272 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs774191944, COSV54217609; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DNAJC16 | c.1357C>T p.R453C | Missense Mutation (SNP) | VAF 129/289 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs777085250; called by muse, mutect2, varscan2
- DNHD1 | c.6187G>A p.G2063S | Missense Mutation (SNP) | VAF 140/330 reads (42%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs757027777; called by muse, varscan2
- DNMT3A | c.2059G>A p.V687I | Missense Mutation (SNP) | VAF 172/337 reads (51%) | SIFT tolerated (0.12); PolyPhen benign (0.171); catalogued as rs1183198167, COSV53038083, COSV53044768; called by muse, mutect2, varscan2
- DOCK4 | c.758C>T p.P253L | Missense Mutation (SNP) | VAF 114/257 reads (44%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs202096330; called by muse, mutect2, varscan2
- DOHH | c.94C>T p.R32C | Missense Mutation (SNP) | VAF 322/699 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs778229924, COSV51744035; called by muse, mutect2, varscan2
- DOLPP1 | c.617G>A p.R206Q | Missense Mutation (SNP) | VAF 113/404 reads (28%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.467); catalogued as rs779266200, COSV59910156; called by muse, mutect2, varscan2
- DPH7 | c.542C>T p.T181M | Missense Mutation (SNP) | VAF 269/515 reads (52%) | SIFT deleterious (0.04); PolyPhen benign (0.276); catalogued as rs922412367; called by muse, mutect2, varscan2
- DPP9 | c.2531G>A p.C844Y (on ENST00000598800; = p.C873Y on NM_139159.5) | Missense Mutation (SNP) | VAF 186/429 reads (43%) | SIFT tolerated (0.55); PolyPhen possibly damaging (0.484); catalogued as rs981667065; called by muse, mutect2, varscan2
- DSCAM | c.1045C>T p.R349C | Missense Mutation (SNP) | VAF 223/487 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs1227425619, COSV68021037; called by muse, mutect2, varscan2
- DSCAML1 | c.3473G>A p.R1158Q (on ENST00000321322; = p.R1098Q on NM_020693.4) | Missense Mutation (SNP) | VAF 192/386 reads (50%) | SIFT tolerated (0.59); PolyPhen possibly damaging (0.726); catalogued as rs953338496; called by muse, varscan2
- DSCAML1 | c.2627G>A p.R876Q (on ENST00000321322; = p.R816Q on NM_020693.4) | Missense Mutation (SNP) | VAF 206/452 reads (46%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.802); catalogued as rs1028890107, COSV58382762; called by muse, mutect2, varscan2
- DST | c.3280C>A p.L1094M (on ENST00000361203 / NM_001374722.1; = p.L768M on NM_001723.6) | Missense Mutation (SNP) | VAF 137/342 reads (40%) | SIFT tolerated (0.05); PolyPhen benign (0.26); catalogued as rs756379041, COSV55031525; called by muse, mutect2, varscan2
- DTNA | c.1250G>A p.R417Q | Missense Mutation (SNP) | VAF 112/226 reads (50%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs774480677, COSV99313992; called by muse, mutect2, varscan2
- DTNB | c.244G>A p.E82K | Missense Mutation (SNP) | VAF 133/277 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as rs768951661, COSV56480745; called by muse, mutect2, varscan2
- DUSP8 | c.169C>T p.R57W | Missense Mutation (SNP) | VAF 357/761 reads (47%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.601); catalogued as rs762548136; called by muse, mutect2, varscan2
- DVL1 | c.599C>T p.T200M | Missense Mutation (SNP) | VAF 172/397 reads (43%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.83); catalogued as rs1254209708, COSV66678109; called by muse, mutect2
- DYNC1H1 | c.10631G>A p.R3544H | Missense Mutation (SNP) | VAF 176/377 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs761216533, COSV64137354; called by muse, mutect2, varscan2
- DYNC1H1 | c.11389G>A p.V3797M | Missense Mutation (SNP) | VAF 234/466 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs760876077, COSV100795447; called by muse, mutect2, varscan2
- DYNC2I2 | c.276del p.V93Cfs*31 | Frame Shift Del (DEL) | VAF 142/682 reads (21%) | catalogued as COSV101021186; called by mutect2, pindel, varscan2
- DYTN | c.1453G>A p.E485K | Missense Mutation (SNP) | VAF 165/361 reads (46%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as COSV71752718; called by muse, mutect2, varscan2
- ECE1 | c.1292G>A p.R431H | Missense Mutation (SNP) | VAF 176/392 reads (45%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.992); catalogued as rs1295873616; called by muse, mutect2, varscan2
- EEF1AKMT4-ECE2 | c.1325_1327del p.K442del | In Frame Del (DEL) | VAF 130/290 reads (45%) | catalogued as rs758872276; called by pindel, varscan2
- EEF2K | c.1175C>A p.S392Y | Missense Mutation (SNP) | VAF 228/470 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as COSV53784849; called by muse, mutect2, varscan2
- EFCAB9 | c.112G>A p.V38M | Missense Mutation (SNP) | VAF 96/228 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.863); catalogued as rs1356894091; called by muse, mutect2, varscan2
- EFEMP2 | c.290C>T p.P97L | Missense Mutation (SNP) | VAF 277/585 reads (47%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as rs779247685; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- EFNA2 | c.154G>A p.A52T | Missense Mutation (SNP) | VAF 205/456 reads (45%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0.015); catalogued as rs757316290, COSV53065375; called by muse, mutect2, varscan2
- EHMT2 | c.2563del p.L855Cfs*36 | Frame Shift Del (DEL) | VAF 188/595 reads (32%) | catalogued as rs1377283633; called by mutect2, varscan2
- ELANE | c.74C>T p.A25V | Missense Mutation (SNP) | VAF 242/489 reads (49%) | SIFT tolerated (0.2); PolyPhen benign (0.218); catalogued as rs1396230082, CM104210, COSV52256451; called by muse, mutect2, varscan2
- ELMOD2 | c.67C>T p.R23* | Nonsense Mutation (SNP) | VAF 149/326 reads (46%) | catalogued as rs750143144; called by muse, mutect2, varscan2
- ELOA | c.745G>A p.G249R | Missense Mutation (SNP) | VAF 172/373 reads (46%) | SIFT tolerated (0.21); PolyPhen benign (0.046); catalogued as rs775582884; called by muse, mutect2, varscan2
- EMC1 | c.227G>A p.R76H | Missense Mutation (SNP) | VAF 111/265 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs748974716, COSV61887025; called by muse, mutect2, varscan2
- EMILIN1 | c.152G>A p.R51Q | Missense Mutation (SNP) | VAF 174/385 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.913); catalogued as rs201575918, COSV66695118; called by muse, mutect2, varscan2
- ENOX1 | c.1579G>A p.E527K | Missense Mutation (SNP) | VAF 122/284 reads (43%) | SIFT tolerated (0.48); PolyPhen benign (0.058); catalogued as rs764001017, COSV54894322; called by muse, mutect2, varscan2
- EPB41L4A | c.133G>A p.V45I | Missense Mutation (SNP) | VAF 39/311 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.047); catalogued as rs528031482, COSV99812389; called by muse, mutect2, varscan2
- EPHB2 | c.2191G>A p.A731T (on ENST00000400191 / NM_001309193.2; = p.A732T on NM_004442.7) | Missense Mutation (SNP) | VAF 198/434 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); catalogued as rs142161660; called by muse, varscan2
- EPHB2 | c.3120del p.F1040Lfs*43 | Frame Shift Del (DEL) | VAF 142/376 reads (38%) | catalogued as rs770822649; called by mutect2, pindel, varscan2
- EPHX1 | c.1324G>A p.A442T | Missense Mutation (SNP) | VAF 239/506 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as rs763600235; called by muse, varscan2
- EPM2AIP1 | c.307G>A p.G103R | Missense Mutation (SNP) | VAF 237/519 reads (46%) | SIFT tolerated (0.32); PolyPhen benign (0.396); catalogued as COSV51621142; called by muse, mutect2, varscan2
- EPN1 | c.59C>T p.A20V | Missense Mutation (SNP) | VAF 230/494 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.552); catalogued as rs774551624; called by muse, mutect2, varscan2
- EPN2 | c.887G>A p.R296H | Missense Mutation (SNP) | VAF 126/279 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.233); catalogued as rs951398293, COSV59061029; called by muse, mutect2, varscan2
- ERN1 | c.2836C>T p.R946W | Missense Mutation (SNP) | VAF 284/551 reads (52%) | SIFT tolerated (0.07); PolyPhen benign (0.11); catalogued as rs200358341; called by muse, mutect2, varscan2
- ERN1 | c.2468C>T p.A823V | Missense Mutation (SNP) | VAF 149/314 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.576); catalogued as rs780870849, COSV70500856; called by muse, mutect2, varscan2
- ERN1 | c.842C>T p.T281M | Missense Mutation (SNP) | VAF 126/255 reads (49%) | SIFT tolerated (0.43); PolyPhen benign (0.003); catalogued as rs370673725; called by muse, mutect2, varscan2
- ESPNL | c.47C>T p.A16V | Missense Mutation (SNP) | VAF 261/531 reads (49%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.448); catalogued as rs759308208, COSV54540000; called by muse, mutect2, varscan2
- ESRP1 | c.878G>A p.R293Q | Missense Mutation (SNP) | VAF 130/299 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64410745; called by muse, mutect2, varscan2
- ESRP1 | c.1535del p.N512Tfs*2 | Frame Shift Del (DEL) | VAF 146/340 reads (43%) | catalogued as rs775950025; called by mutect2, varscan2
- EVI2B | c.593del p.N198Tfs*6 | Frame Shift Del (DEL) | VAF 167/414 reads (40%) | catalogued as rs765136869; called by mutect2, pindel, varscan2
- EVX2 | c.913G>A p.A305T | Missense Mutation (SNP) | VAF 244/551 reads (44%) | SIFT tolerated (0.2); PolyPhen benign (0.005); catalogued as rs760847501; called by muse, varscan2
- EXO5 | c.652G>A p.V218I | Missense Mutation (SNP) | VAF 157/351 reads (45%) | SIFT deleterious (0.04); PolyPhen benign (0.019); catalogued as rs781656662; called by muse, mutect2, varscan2
- EXTL3 | c.839G>A p.R280H | Missense Mutation (SNP) | VAF 195/374 reads (52%) | SIFT tolerated (0.13); PolyPhen benign (0.106); catalogued as rs139633425, COSV55038590; called by muse, varscan2
- EYS | c.1372C>T p.L458F | Missense Mutation (SNP) | VAF 133/288 reads (46%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as rs760342117; called by muse, mutect2, varscan2
- FAM133B | c.391C>T p.R131W | Missense Mutation (SNP) | VAF 69/173 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.625); catalogued as rs772730489; called by muse, mutect2, varscan2
- FAM13B | c.1657C>T p.R553* | Nonsense Mutation (SNP) | VAF 122/223 reads (55%) | catalogued as rs756297490, COSV50365444; called by muse, mutect2, varscan2
- FAM166A | c.558dup p.A187Rfs*23 | Frame Shift Ins (INS) | VAF 104/255 reads (41%) | catalogued as rs766839703; called by mutect2, pindel
- FAM168A | c.68C>T p.T23M | Missense Mutation (SNP) | VAF 163/409 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.725); catalogued as rs568533341; called by muse, mutect2, varscan2
- FAM170B | c.392C>T p.P131L | Missense Mutation (SNP) | VAF 227/473 reads (48%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.654); catalogued as rs1196785528, COSV100308476; called by muse, mutect2, varscan2
- FAM171A1 | c.1804G>A p.V602I | Missense Mutation (SNP) | VAF 195/408 reads (48%) | SIFT tolerated (0.2); PolyPhen benign (0.04); catalogued as rs574266280; called by muse, mutect2, varscan2
- FAM189A1 | c.728del p.P243Hfs*71 | Frame Shift Del (DEL) | VAF 296/746 reads (40%) | catalogued as COSV99720881; called by pindel, varscan2
- FAM189A1 | c.638C>T p.P213L | Missense Mutation (SNP) | VAF 167/364 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs768291963; called by muse, varscan2
- FAM71A | c.194G>A p.R65H | Missense Mutation (SNP) | VAF 219/487 reads (45%) | SIFT tolerated (0.08); PolyPhen benign (0.099); catalogued as rs777022954, COSV54235101, COSV54236851; called by muse, mutect2, varscan2
- FAM83C | c.2231G>A p.R744H | Missense Mutation (SNP) | VAF 89/196 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs561188076, COSV65583802; called by muse, mutect2, varscan2
- FAM90A1 | c.955G>A p.A319T | Missense Mutation (SNP) | VAF 169/387 reads (44%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as rs751330423, COSV56711564; called by muse, mutect2, varscan2
- FAM98C | c.889C>T p.R297C | Missense Mutation (SNP) | VAF 195/386 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs768768718; called by muse, mutect2, varscan2
- FANCE | c.1588G>A p.A530T | Missense Mutation (SNP) | VAF 107/254 reads (42%) | SIFT tolerated (0.1); PolyPhen benign (0.134); catalogued as rs377415237; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FASN | c.6487C>T p.R2163C | Missense Mutation (SNP) | VAF 256/613 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1031448244; called by muse, mutect2, varscan2
- FAT1 | c.11737G>A p.A3913T | Missense Mutation (SNP) | VAF 158/339 reads (47%) | SIFT tolerated (0.28); PolyPhen benign (0.017); catalogued as rs773650405, COSV101499198; called by muse, mutect2, varscan2
- FAT2 | c.9610G>A p.V3204I | Missense Mutation (SNP) | VAF 329/617 reads (53%) | SIFT tolerated (0.05); PolyPhen benign (0.213); catalogued as rs140898888; called by muse, mutect2, varscan2
- FAT3 | c.3307G>A p.A1103T | Missense Mutation (SNP) | VAF 91/215 reads (42%) | SIFT tolerated (0.64); PolyPhen benign (0.083); catalogued as rs774983511, COSV53121160; called by muse, mutect2, varscan2
- FBF1 | c.2870G>A p.R957Q (on ENST00000586717; = p.R972Q on NM_001319193.1) | Missense Mutation (SNP) | VAF 295/650 reads (45%) | SIFT tolerated (0.16); PolyPhen benign (0.03); catalogued as rs553617516; called by muse, mutect2, varscan2
- FBN1 | c.74C>T p.A25V | Missense Mutation (SNP) | VAF 170/497 reads (34%) | SIFT tolerated (0.57); PolyPhen probably damaging (0.939); catalogued as COSV57325037; called by muse, mutect2, varscan2
- FBN2 | c.2779G>A p.A927T | Missense Mutation (SNP) | VAF 166/320 reads (52%) | SIFT deleterious (0.03); PolyPhen benign (0.41); catalogued as rs863223559; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FBXL18 | c.863G>A p.R288H | Missense Mutation (SNP) | VAF 207/424 reads (49%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.843); catalogued as rs775995098, COSV66665310, COSV66668783; called by muse, mutect2, varscan2
- FBXO24 | c.1465C>T p.R489C (on ENST00000241071 / NM_033506.3; = p.R527C on NM_012172.5) | Missense Mutation (SNP) | VAF 241/557 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.328); catalogued as rs762948451, COSV53828731; called by muse, mutect2, varscan2
- FBXO41 | c.1295C>T p.P432L | Missense Mutation (SNP) | VAF 283/623 reads (45%) | SIFT tolerated (0.22); PolyPhen benign (0.029); catalogued as rs879431027; called by muse, mutect2, varscan2
- FBXW11 | c.1457G>A p.R486H | Missense Mutation (SNP) | VAF 93/180 reads (52%) | SIFT tolerated (0.23); PolyPhen benign (0.102); catalogued as rs773518789, COSV51612643; called by muse, mutect2, varscan2
- FGD2 | c.358C>T p.R120C | Missense Mutation (SNP) | VAF 175/371 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs779897171; called by muse, mutect2, varscan2
- FGD3 | c.1169G>A p.R390H | Missense Mutation (SNP) | VAF 146/321 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs770049768; called by muse, mutect2, varscan2
- FGD4 | c.2046C>T p.D682= | Splice Region (SNP) | VAF 133/277 reads (48%) | catalogued as rs371833051, COSV56786822; called by muse, mutect2
- FGD5 | c.3125G>A p.R1042H | Missense Mutation (SNP) | VAF 181/374 reads (48%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.633); catalogued as rs372788718; called by muse, mutect2, varscan2
- FGF8 | c.623G>A p.R208H (on ENST00000344255 / NM_033164.4; = p.R190H on NM_006119.6) | Missense Mutation (SNP) | VAF 321/702 reads (46%) | SIFT tolerated (0.21); PolyPhen benign (0.009); catalogued as rs769174862; called by muse, mutect2, varscan2
- FGFR4 | c.1330G>A p.A444T | Missense Mutation (SNP) | VAF 260/536 reads (49%) | SIFT tolerated (0.27); PolyPhen benign (0.048); catalogued as rs778723081, COSV52804574, COSV52807189; called by muse, mutect2, varscan2
- FIBCD1 | c.1301G>A p.G434D | Missense Mutation (SNP) | VAF 70/770 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs765322332; called by muse, mutect2
- FILIP1 | c.3277C>T p.R1093* | Nonsense Mutation (SNP) | VAF 121/253 reads (48%) | catalogued as rs752395530, COSV52723288, COSV52733745; called by muse, mutect2, varscan2
- FILIP1L | c.1034G>A p.R345Q (on ENST00000354552 / NM_182909.3; = p.R105Q on NM_014890.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 219/387 reads (57%) | SIFT tolerated (0.92); PolyPhen benign (0.13); catalogued as rs374961168; called by muse, mutect2, varscan2
- FIZ1 | c.770C>T p.A257V | Missense Mutation (SNP) | VAF 332/687 reads (48%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as rs1028650315; called by muse, mutect2
- FKRP | c.797C>T p.A266V | Missense Mutation (SNP) | VAF 262/523 reads (50%) | SIFT tolerated (0.3); PolyPhen benign (0.001); catalogued as rs1276654268; called by muse, mutect2, varscan2
- FLG | c.6776G>A p.R2259Q | Missense Mutation (SNP) | VAF 258/553 reads (47%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as rs542918091, COSV64246345; called by muse, mutect2
- FLG | c.1363C>T p.R455C | Missense Mutation (SNP) | VAF 209/424 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as rs757922040, COSV100911849; called by muse, varscan2
- FLT4 | c.1975C>T p.R659C | Missense Mutation (SNP) | VAF 171/356 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.849); catalogued as COSV99986624; called by muse, mutect2, varscan2
- FMN2 | c.2848G>A p.G950R | Missense Mutation (SNP) | VAF 133/303 reads (44%) | SIFT tolerated, low confidence (0.11); PolyPhen possibly damaging (0.822); catalogued as rs1276801853; called by muse, mutect2, varscan2
- FN1 | c.5741C>T p.T1914I | Missense Mutation (SNP) | VAF 137/301 reads (46%) | SIFT tolerated (0.37); PolyPhen probably damaging (0.999); catalogued as rs756331026; called by muse, mutect2, varscan2
- FN1 | c.3082C>T p.R1028* | Nonsense Mutation (SNP) | VAF 194/408 reads (48%) | catalogued as COSV60564371; called by muse, mutect2, varscan2
- FNDC11 | c.131G>A p.R44H | Missense Mutation (SNP) | VAF 259/484 reads (54%) | SIFT deleterious (0.05); PolyPhen benign (0.029); catalogued as rs779082342; called by muse, mutect2, varscan2
- FNDC11 | c.688G>A p.V230I | Missense Mutation (SNP) | VAF 223/466 reads (48%) | SIFT tolerated (0.08); PolyPhen benign (0.226); catalogued as rs752740200, COSV64442580; called by muse, varscan2
- FNDC3B | c.1960G>A p.G654R | Missense Mutation (SNP) | VAF 101/223 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1560089040; called by muse, mutect2, varscan2
- FNDC4 | c.629C>T p.P210L | Missense Mutation (SNP) | VAF 164/394 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.67); catalogued as rs1356804969; called by muse, mutect2, varscan2
- FOXF1 | c.1085del p.G362Afs*17 | Frame Shift Del (DEL) | VAF 221/539 reads (41%) | catalogued as COSV52287150; called by mutect2, pindel, varscan2
- FOXI1 | c.1045G>A p.G349R | Missense Mutation (SNP) | VAF 219/461 reads (48%) | SIFT tolerated (0.12); PolyPhen benign (0.383); catalogued as rs371742098, COSV100089553; called by muse, mutect2, varscan2
- FOXN3 | c.1237G>A p.G413R (on ENST00000261302; = p.G391R on NM_005197.4) | Missense Mutation (SNP) | VAF 212/492 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.797); catalogued as rs201853361; called by muse, mutect2, varscan2
- FRA10AC1 | c.76del p.R26Gfs*44 | Frame Shift Del (DEL) | VAF 90/230 reads (39%) | catalogued as rs755202796; called by mutect2, pindel, varscan2
- FRAS1 | c.6376C>T p.R2126C | Missense Mutation (SNP) | VAF 192/398 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.634); catalogued as rs779986441; called by muse, varscan2
- FRAT2 | c.269C>T p.A90V | Missense Mutation (SNP) | VAF 277/513 reads (54%) | SIFT deleterious (0.02); PolyPhen benign (0.101); catalogued as rs909251895; called by muse, mutect2, varscan2
- FREM3 | c.2392C>T p.R798W | Missense Mutation (SNP) | VAF 207/429 reads (48%) | SIFT tolerated (0.08); PolyPhen benign (0.065); catalogued as rs776491489; called by muse, mutect2, varscan2
- FTCD | c.611G>A p.R204Q | Missense Mutation (SNP) | VAF 212/448 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs144080295, COSV52423529; called by muse, varscan2
- FUT11 | c.1204G>A p.E402K | Missense Mutation (SNP) | VAF 216/467 reads (46%) | SIFT tolerated (0.26); PolyPhen benign (0.027); catalogued as rs1191668812; called by muse, varscan2
- FYCO1 | c.1922C>T p.A641V | Missense Mutation (SNP) | VAF 284/565 reads (50%) | SIFT tolerated (0.05); PolyPhen benign (0.006); catalogued as rs773743760; called by muse, mutect2, varscan2
- FZD7 | c.1520C>T p.T507M | Missense Mutation (SNP) | VAF 279/580 reads (48%) | SIFT tolerated (0.25); PolyPhen benign (0.046); catalogued as COSV53808675; called by muse, mutect2, varscan2
- FZR1 | c.541G>A p.A181T | Missense Mutation (SNP) | VAF 256/525 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1293528826, COSV58053277; called by muse, mutect2, varscan2
- G6PD | c.505G>A p.V169M | Missense Mutation (SNP) | VAF 10/243 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as rs782436684; called by muse, mutect2
- GABBR1 | c.1721dup p.A575Sfs*2 | Frame Shift Ins (INS) | VAF 154/326 reads (47%) | catalogued as rs777471402; called by mutect2, varscan2
- GABBR1 | c.1253C>T p.A418V | Missense Mutation (SNP) | VAF 287/664 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV100589754; called by muse, mutect2, varscan2
- GABBR2 | c.1822G>A p.D608N | Missense Mutation (SNP) | VAF 160/316 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs978945843, COSV52309784; called by muse, mutect2, varscan2
- GABRB2 | c.1009C>T p.R337C | Missense Mutation (SNP) | VAF 180/330 reads (55%) | SIFT deleterious (0.05); PolyPhen benign (0.031); catalogued as rs777778428, COSV50905153; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GABRG1 | c.995C>T p.A332V | Missense Mutation (SNP) | VAF 133/282 reads (47%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs756517614, COSV54954933; called by muse, mutect2, varscan2
- GALNT2 | c.80del p.G27Afs*115 | Frame Shift Del (DEL) | VAF 235/725 reads (32%) | catalogued as rs1553309006; called by pindel, varscan2
- GAREM1 | c.2462G>A p.R821Q (on ENST00000269209 / NM_001242409.2; = p.R820Q on NM_022751.3) | Missense Mutation (SNP) | VAF 198/384 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.54); catalogued as rs756156267; called by muse, mutect2, varscan2
- GARRE1 | c.127G>A p.A43T | Missense Mutation (SNP) | VAF 209/773 reads (27%) | SIFT tolerated, low confidence (0.07); PolyPhen probably damaging (0.993); catalogued as COSV100209253; called by muse, mutect2, varscan2
- GAS2L2 | c.2433del p.K812Rfs*5 | Frame Shift Del (DEL) | VAF 206/628 reads (33%) | catalogued as rs782288149; called by pindel, varscan2
- GATA4 | c.779G>A p.R260Q | Missense Mutation (SNP) | VAF 131/311 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.451); catalogued as rs1245034279, COSV100633118; called by muse, mutect2, varscan2
- GATAD1 | c.604G>A p.A202T | Missense Mutation (SNP) | VAF 88/183 reads (48%) | SIFT deleterious (0.02); PolyPhen benign (0.148); catalogued as rs564747350, COSV99843623; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GATAD2A | c.1757C>T p.T586M | Missense Mutation (SNP) | VAF 146/331 reads (44%) | SIFT tolerated (0.25); PolyPhen benign (0.391); catalogued as rs760258128; called by muse, mutect2, varscan2
- GCN1 | c.937C>T p.R313C | Missense Mutation (SNP) | VAF 137/321 reads (43%) | SIFT tolerated (0.06); PolyPhen benign (0.123); catalogued as rs750521946, COSV100325005; called by muse, mutect2, varscan2
- GEMIN5 | c.3026C>T p.A1009V | Missense Mutation (SNP) | VAF 129/296 reads (44%) | SIFT tolerated (0.33); PolyPhen benign (0.027); catalogued as rs371819928; called by muse, mutect2, varscan2
- GFAP | c.1289G>T p.R430L | Missense Mutation (SNP) | VAF 151/297 reads (51%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as CM134096; called by muse, mutect2, varscan2
- GFRA1 | c.671G>A p.R224Q | Missense Mutation (SNP) | VAF 227/500 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs1005537154, COSV100815894, COSV62602441; called by muse, mutect2, varscan2
- GINS1 | c.515del p.N172Ifs*14 | Frame Shift Del (DEL) | VAF 78/188 reads (41%) | catalogued as rs750227570; called by mutect2, varscan2
- GLB1L2 | c.1753C>T p.R585C | Missense Mutation (SNP) | VAF 173/334 reads (52%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs746777635; called by muse, mutect2, varscan2
- GLI2 | c.2384C>T p.T795M (on ENST00000361492 / NM_001374353.1; = p.T812M on NM_005270.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 407/795 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs773308985, COSV58052651; called by muse, mutect2, varscan2
- GLIS3 | c.548C>T p.P183L | Missense Mutation (SNP) | VAF 145/449 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs143836372; called by muse, mutect2, varscan2
- GLOD4 | c.250G>A p.A84T (on ENST00000301328 / NM_001366247.1; = p.A69T on NM_016080.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 179/390 reads (46%) | SIFT tolerated (0.24); PolyPhen benign (0.015); catalogued as rs756805516; called by muse, mutect2, varscan2
- GLRB | c.752-1G>T p.X251_splice | Splice Site (SNP) | VAF 94/189 reads (50%) | catalogued as COSV52420477; called by muse, mutect2, varscan2
- GNAI2 | c.427C>T p.R143C | Missense Mutation (SNP) | VAF 203/409 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs782805532; called by muse, mutect2, varscan2
- GNL3 | c.1372G>A p.G458S | Missense Mutation (SNP) | VAF 149/337 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.537); catalogued as rs372615484; called by muse, mutect2, varscan2
- GPR101 | c.1099G>A p.V367I | Missense Mutation (SNP) | VAF 265/266 reads (100%) | SIFT tolerated (0.8); PolyPhen benign (0.003); catalogued as rs144604669, COSV53239022; called by muse, mutect2, varscan2
- GPR12 | c.65C>T p.A22V | Missense Mutation (SNP) | VAF 179/360 reads (50%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as COSV67344032; called by muse, mutect2, varscan2
- GPR135 | c.1198C>T p.R400C | Missense Mutation (SNP) | VAF 256/565 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV67749879; called by muse, mutect2, varscan2
- GPR158 | c.2270G>A p.R757H | Missense Mutation (SNP) | VAF 190/378 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs557143314, COSV66271826, COSV66282257; called by muse, mutect2, varscan2
- GPR174 | c.374G>A p.R125H | Missense Mutation (SNP) | VAF 221/221 reads (100%) | SIFT tolerated (0.07); PolyPhen benign (0.031); catalogued as rs200548821, CM136727; called by muse, mutect2, varscan2
- GPR62 | c.121C>T p.R41C | Missense Mutation (SNP) | VAF 318/694 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV59055832; called by muse, mutect2, varscan2
- GPR89A | c.337dup p.S113Ffs*71 | Frame Shift Ins (INS) | VAF 74/233 reads (32%) | catalogued as rs1256102621; called by mutect2, pindel, varscan2
- GPRC5B | c.244C>T p.P82S | Missense Mutation (SNP) | VAF 218/446 reads (49%) | SIFT deleterious (0.01); PolyPhen benign (0.371); catalogued as rs530209030; called by muse, mutect2, varscan2
- GPRIN2 | c.1334G>A p.R445Q | Missense Mutation (SNP) | VAF 192/1226 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.112); catalogued as rs781936680; called by muse, mutect2, varscan2
- GRHPR | c.469G>A p.G157S | Missense Mutation (SNP) | VAF 37/301 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.979); catalogued as rs774233908, COSV58944706; called by muse, mutect2, varscan2
- GRID1 | c.857C>T p.P286L | Missense Mutation (SNP) | VAF 170/372 reads (46%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.999); catalogued as rs760195348, COSV60025408; called by muse, mutect2, varscan2
- GRIN3B | c.520G>A p.V174I | Missense Mutation (SNP) | VAF 350/730 reads (48%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as rs1369396143; called by muse, mutect2, varscan2
- GRM1 | c.544del p.Q182Rfs*11 | Frame Shift Del (DEL) | VAF 157/428 reads (37%) | catalogued as rs1421731846; called by pindel, varscan2
- GRM1 | c.1561C>T p.R521W | Missense Mutation (SNP) | VAF 147/316 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs746660819, COSV51174083; called by muse, mutect2, varscan2
- GRM5 | c.3497C>T p.P1166L (on ENST00000305447 / NM_001143831.2; = p.P1134L on NM_000842.4) | Missense Mutation (SNP) | VAF 232/454 reads (51%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.878); catalogued as rs1317020135; called by muse, mutect2, varscan2
- GRXCR2 | c.58C>T p.R20* | Nonsense Mutation (SNP) | VAF 195/419 reads (47%) | catalogued as rs762841261; called by muse, mutect2, varscan2
- GSG1L | c.898C>T p.R300* (on ENST00000447459 / NM_001109763.2; = p.R145* on NM_144675.2) | Nonsense Mutation (SNP) | VAF 138/284 reads (49%) | catalogued as rs763637151, COSV101093691, COSV66580614; called by muse, mutect2, varscan2
- GSN | c.743G>A p.R248Q | Missense Mutation (SNP) | VAF 81/472 reads (17%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs745312507; called by muse, mutect2, varscan2
- GTF2IRD2B | c.454G>A p.V152I | Missense Mutation (SNP) | VAF 59/256 reads (23%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.031); catalogued as rs782552756; called by muse, mutect2, varscan2
- GTF2IRD2B | c.1919C>T p.A640V | Missense Mutation (SNP) | VAF 193/436 reads (44%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.97); catalogued as rs202112649; called by muse, mutect2, varscan2
- GTF3C1 | c.1907+1G>A p.X636_splice | Splice Site (SNP) | VAF 118/233 reads (51%) | catalogued as COSV62240602; called by muse, mutect2, varscan2
- GUCY2C | c.2027G>A p.R676Q | Missense Mutation (SNP) | VAF 148/317 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs376847075; called by muse, mutect2, varscan2
- GYPC | c.245G>A p.R82H | Missense Mutation (SNP) | VAF 140/328 reads (43%) | SIFT tolerated (0.51); PolyPhen benign (0.001); catalogued as rs149400883; called by muse, mutect2, varscan2
- H4C9 | c.130G>A p.V44M | Missense Mutation (SNP) | VAF 227/463 reads (49%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.914); catalogued as COSV100574868; called by muse, mutect2, varscan2
- HAPLN3 | c.736G>A p.G246S | Missense Mutation (SNP) | VAF 330/649 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs773603379; called by muse, mutect2, varscan2
- HAPLN3 | c.389C>T p.S130L | Missense Mutation (SNP) | VAF 257/518 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs199664746, COSV62084501; called by muse, mutect2, varscan2
- HAS1 | c.626C>T p.A209V | Missense Mutation (SNP) | VAF 428/846 reads (51%) | SIFT deleterious (0.04); PolyPhen benign (0.338); catalogued as COSV55787516; called by muse, mutect2
- HAS3 | c.439G>A p.G147S | Missense Mutation (SNP) | VAF 287/593 reads (48%) | SIFT tolerated (0.14); PolyPhen benign (0.196); catalogued as rs746052927, COSV54706161; called by muse, mutect2
- HCK | c.998C>T p.T333M | Missense Mutation (SNP) | VAF 135/291 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs757866724, COSV99393939, COSV99394128; called by muse, mutect2, varscan2
- HCN1 | c.1511G>A p.R504Q | Missense Mutation (SNP) | VAF 132/273 reads (48%) | SIFT deleterious (0.03); PolyPhen benign (0.197); catalogued as COSV57518436; called by muse, mutect2, varscan2
- HCN3 | c.1213G>A p.E405K | Missense Mutation (SNP) | VAF 197/427 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.733); catalogued as rs1481497043; called by muse, mutect2, varscan2
- HCRTR2 | c.910C>T p.R304W | Missense Mutation (SNP) | VAF 143/341 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.532); catalogued as COSV63796162; called by muse, mutect2, varscan2
- HDGFL1 | c.377G>A p.G126D | Missense Mutation (SNP) | VAF 273/535 reads (51%) | SIFT tolerated (0.26); PolyPhen benign (0.006); catalogued as rs1184843939, COSV57751246; called by muse, mutect2, varscan2
- HEATR5A | c.5386C>T p.R1796W | Missense Mutation (SNP) | VAF 155/345 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.78); catalogued as rs372690763; called by muse, mutect2, varscan2
- HECTD4 | c.11486C>T p.T3829M | Missense Mutation (SNP) | VAF 155/300 reads (52%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs746255951, COSV66395002; called by muse, mutect2, varscan2
- HECTD4 | c.3761C>T p.P1254L | Missense Mutation (SNP) | VAF 143/339 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs1208722334; called by muse, mutect2, varscan2
- HECW1 | c.1670G>A p.R557Q | Missense Mutation (SNP) | VAF 211/425 reads (50%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.992); catalogued as rs532143087, COSV67829190; called by muse, mutect2, varscan2
- HEG1 | c.695C>T p.S232L | Missense Mutation (SNP) | VAF 238/438 reads (54%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0); catalogued as rs1187475335; called by muse, mutect2, varscan2
- HELZ2 | c.6271G>A p.V2091I (on ENST00000467148 / NM_001037335.2; = p.V1522I on NM_033405.3) | Missense Mutation (SNP) | VAF 166/364 reads (46%) | SIFT tolerated (0.3); PolyPhen benign (0.015); catalogued as rs1024311463, COSV71296137; called by muse, varscan2
- HEMGN | c.585G>T p.K195N | Missense Mutation (SNP) | VAF 226/429 reads (53%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as COSV52325922; called by muse, mutect2, varscan2
- HERC1 | c.12728del p.K4243Rfs*12 | Frame Shift Del (DEL) | VAF 147/389 reads (38%) | catalogued as rs1487761198; called by mutect2, pindel, varscan2
- HERC1 | c.12001T>G p.L4001V | Missense Mutation (SNP) | VAF 146/320 reads (46%) | SIFT tolerated (0.15); PolyPhen benign (0.397); catalogued as rs1177171990; called by muse, mutect2, varscan2
- HERC5 | c.1812del p.F604Lfs*2 | Frame Shift Del (DEL) | VAF 149/386 reads (39%) | catalogued as rs1256699530; called by mutect2, pindel, varscan2
- HERC6 | c.1109G>A p.R370H | Missense Mutation (SNP) | VAF 80/172 reads (47%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as rs371365965; called by muse, mutect2, varscan2
- HEXD | c.1196G>A p.R399H (on ENST00000327949 / NM_001369487.1; = p.A429T on NM_173620.3) | Missense Mutation (SNP) | VAF 177/390 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs760603638, COSV60062772; called by muse, mutect2, varscan2
- HEYL | c.736C>T p.R246W | Missense Mutation (SNP) | VAF 321/635 reads (51%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as rs778733690, COSV65722022; called by muse, mutect2, varscan2
- HGF | c.74C>T p.A25V | Missense Mutation (SNP) | VAF 109/248 reads (44%) | SIFT tolerated (0.81); PolyPhen benign (0.034); catalogued as COSV55948803; called by muse, mutect2, varscan2
- HHLA1 | c.994G>A p.V332M | Missense Mutation (SNP) | VAF 143/304 reads (47%) | SIFT tolerated (0.2); PolyPhen benign (0.006); catalogued as rs118152489; called by muse, mutect2, varscan2
- HHLA2 | c.311C>T p.A104V | Missense Mutation (SNP) | VAF 143/334 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); catalogued as rs771206254, COSV63315976; called by muse, mutect2, varscan2
- HIF1A | c.2260C>T p.R754C | Missense Mutation (SNP) | VAF 144/314 reads (46%) | SIFT deleterious (0.02); PolyPhen benign (0.018); catalogued as rs1251468432, COSV60189211, COSV60191098; called by muse, mutect2, varscan2
- HIP1R | c.26C>T p.A9V | Missense Mutation (SNP) | VAF 220/453 reads (49%) | SIFT tolerated (0.05); PolyPhen benign (0.013); catalogued as rs1476901365; called by muse, varscan2
- HKDC1 | c.751G>A p.D251N | Missense Mutation (SNP) | VAF 225/440 reads (51%) | SIFT tolerated (0.07); PolyPhen benign (0.078); catalogued as rs140372000; called by muse, mutect2, varscan2
- HMCN1 | c.958C>T p.R320* | Nonsense Mutation (SNP) | VAF 109/221 reads (49%) | catalogued as rs776450081, COSV54876415; called by muse, mutect2, varscan2
- HMCN1 | c.6250G>A p.V2084M | Missense Mutation (SNP) | VAF 138/270 reads (51%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs577324065, COSV54933716; called by muse, mutect2, varscan2
- HMMR | c.1998del p.K666Nfs*11 | Frame Shift Del (DEL) | VAF 82/194 reads (42%) | catalogued as rs761272507; called by mutect2, varscan2
- HNRNPM | c.1285C>T p.R429C | Missense Mutation (SNP) | VAF 341/704 reads (48%) | SIFT deleterious (0.04); PolyPhen benign (0.353); catalogued as rs770127136, COSV99725821; called by muse, mutect2, varscan2
- HOXA6 | c.63_65del p.F21del | In Frame Del (DEL) | VAF 150/361 reads (42%) | catalogued as rs776564519; called by pindel, varscan2
- HOXB3 | c.1097C>T p.A366V | Missense Mutation (SNP) | VAF 210/439 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.596); catalogued as rs1165198439; called by muse, mutect2, varscan2
- HSDL1 | c.295C>T p.R99W | Missense Mutation (SNP) | VAF 146/286 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs771834957, COSV99550291; called by muse, mutect2, varscan2
- HSPG2 | c.5656C>T p.R1886C | Missense Mutation (SNP) | VAF 213/400 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs566129415, COSV65969378; called by muse, mutect2, varscan2
- HTT | c.5827G>A p.V1943I | Missense Mutation (SNP) | VAF 197/413 reads (48%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as rs201639415, COSV100750329; called by muse, mutect2, varscan2
- HYDIN | c.7081C>T p.R2361W | Missense Mutation (SNP) | VAF 18/45 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as rs755200815; called by mutect2, varscan2
- ICAM1 | c.859C>T p.R287W | Missense Mutation (SNP) | VAF 138/477 reads (29%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as rs989473316, COSV53426543; called by muse, mutect2, varscan2
- IFNL3 | c.443G>A p.R148Q | Missense Mutation (SNP) | VAF 214/462 reads (46%) | SIFT tolerated (0.5); PolyPhen benign (0.019); catalogued as rs146276429, COSV69829889; called by muse, mutect2, varscan2
- IGF1R | c.2273C>T p.T758M | Missense Mutation (SNP) | VAF 194/422 reads (46%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.535); catalogued as rs773205989; called by muse, mutect2, varscan2
- IGHMBP2 | c.1913C>T p.T638M | Missense Mutation (SNP) | VAF 181/364 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as rs747465472, COSV99661657; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- IGKV1OR2-108 | c.299T>C p.L100P | Missense Mutation (SNP) | VAF 102/361 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs1490407053; called by muse, mutect2, varscan2
- IGKV2D-26 | c.104C>A p.P35H | Missense Mutation (SNP) | VAF 109/239 reads (46%) | SIFT tolerated (0.09); PolyPhen benign (0.046); catalogued as rs1171015961; called by muse, mutect2, varscan2
- IGSF22 | c.1567G>A p.V523M | Missense Mutation (SNP) | VAF 181/382 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.467); catalogued as rs372284868; called by muse, mutect2, varscan2
- IKZF1 | c.1453G>A p.G485S | Missense Mutation (SNP) | VAF 182/387 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58792511; called by muse, mutect2, varscan2
- IL17RA | c.896C>T p.A299V | Missense Mutation (SNP) | VAF 166/325 reads (51%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs746356951; called by muse, mutect2, varscan2
- IL17RC | c.1099G>A p.A367T (on ENST00000295981 / NM_153461.4; = p.A281T on NM_032732.6 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 187/385 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs776089912, COSV55974769; called by muse, mutect2, varscan2
- IL17RE | c.1435C>T p.R479C | Missense Mutation (SNP) | VAF 190/437 reads (43%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.548); catalogued as rs992398278; called by muse, mutect2, varscan2
- IL25 | c.487C>T p.R163C | Missense Mutation (SNP) | VAF 234/491 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.825); catalogued as rs767350854, COSV59306867; called by muse, mutect2
- IL32 | c.424G>A p.A142T (on ENST00000396890 / NM_001308078.4; = p.A96T on NM_004221.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 82/366 reads (22%) | SIFT tolerated (0.57); PolyPhen benign (0.028); catalogued as rs1402458039, COSV99145452; called by muse, mutect2
- IL36A | c.112C>T p.R38C | Missense Mutation (SNP) | VAF 21/259 reads (8%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as rs751426211, COSV52082570; called by muse, mutect2
- IL5 | c.328C>T p.R110W | Missense Mutation (SNP) | VAF 111/248 reads (45%) | SIFT tolerated (0.18); PolyPhen benign (0.102); catalogued as rs201223432, COSV51504888; called by muse, mutect2, varscan2
- IL6ST | c.671C>T p.P224L | Missense Mutation (SNP) | VAF 85/197 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs763726030; called by muse, mutect2, varscan2
- INCENP | c.2233C>T p.R745W (on ENST00000394818 / NM_001040694.2; = p.R741W on NM_020238.3) | Missense Mutation (SNP) | VAF 195/390 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.685); catalogued as rs550675425, COSV53917435; called by muse, mutect2, varscan2
- INHBA | c.257C>T p.A86V | Missense Mutation (SNP) | VAF 232/464 reads (50%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as rs749750926; called by muse, mutect2, varscan2
- INPP4B | c.424C>T p.R142* | Nonsense Mutation (SNP) | VAF 73/151 reads (48%) | catalogued as rs1330358087, COSV99526997; called by muse, mutect2, varscan2
- INSL3 | c.143G>C p.G48A | Missense Mutation (SNP) | VAF 323/690 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.713); catalogued as rs1000129052, COSV100427628; called by muse, mutect2
- INTS13 | c.1489dup p.T497Nfs*7 | Frame Shift Ins (INS) | VAF 100/296 reads (34%) | catalogued as rs1363242314; called by pindel, varscan2
- INTS5 | c.1406G>A p.R469H | Missense Mutation (SNP) | VAF 223/489 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.556); catalogued as rs778593558; called by muse, mutect2, varscan2
- INTU | c.1934G>A p.R645Q | Missense Mutation (SNP) | VAF 164/311 reads (53%) | SIFT tolerated (0.17); PolyPhen benign (0.034); catalogued as rs758939107, COSV58871580; called by muse, mutect2, varscan2
- INVS | c.1607G>A p.R536H | Missense Mutation (SNP) | VAF 200/378 reads (53%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs752692382, COSV104389905; called by muse, mutect2, varscan2
- IPO13 | c.1997G>A p.R666Q | Missense Mutation (SNP) | VAF 141/287 reads (49%) | SIFT tolerated (0.27); PolyPhen benign (0.001); catalogued as rs1339860243, COSV64893732; called by muse, mutect2, varscan2
- IQSEC3 | c.1462G>A p.V488I (on ENST00000538872 / NM_001170738.2; = p.V185I on NM_015232.1) | Missense Mutation (SNP) | VAF 245/545 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.688); catalogued as COSV58284848; called by muse, mutect2, varscan2
- IRAG1 | c.361C>T p.R121* | Nonsense Mutation (SNP) | VAF 119/276 reads (43%) | catalogued as rs774988512, COSV101350891, COSV70212604; called by muse, mutect2, varscan2
- IRGQ | c.895G>A p.A299T | Missense Mutation (SNP) | VAF 263/528 reads (50%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.744); catalogued as COSV60670227; called by muse, mutect2, varscan2
- IRS1 | c.2576C>T p.T859M | Missense Mutation (SNP) | VAF 244/522 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs756434990, COSV59340025; called by muse, mutect2, varscan2
- IRS2 | c.2100_2105del p.A701_V702del | In Frame Del (DEL) | VAF 324/836 reads (39%) | catalogued as rs1566413592; called by pindel, varscan2
- IRX2 | c.253G>A p.A85T | Missense Mutation (SNP) | VAF 73/154 reads (47%) | SIFT deleterious (0.02); PolyPhen benign (0.022); catalogued as COSV100121697; called by muse, mutect2, varscan2
- ISLR2 | c.1351G>A p.A451T | Missense Mutation (SNP) | VAF 277/573 reads (48%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as rs1395632632, COSV100679355; called by muse, mutect2, varscan2
- ITGAD | c.2576G>A p.R859H | Missense Mutation (SNP) | VAF 150/316 reads (47%) | SIFT tolerated (0.08); PolyPhen benign (0.109); catalogued as rs369360258; called by muse, mutect2, varscan2
- ITGAD | c.3388C>T p.R1130C | Missense Mutation (SNP) | VAF 113/259 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs201870715; called by muse, mutect2, varscan2
- ITIH3 | c.2585C>T p.T862M | Missense Mutation (SNP) | VAF 135/282 reads (48%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.451); catalogued as rs762645645, COSV99820054; called by muse, mutect2, varscan2
- ITPR2 | c.4205C>T p.P1402L | Missense Mutation (SNP) | VAF 130/267 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs781558920; called by muse, varscan2
- ITPR2 | c.3020C>T p.A1007V | Missense Mutation (SNP) | VAF 155/315 reads (49%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as rs535598972, COSV67277748; called by muse, mutect2, varscan2
- ITPR3 | c.954G>T p.E318D | Missense Mutation (SNP) | VAF 154/319 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.814); catalogued as rs778240357, COSV65415980; called by muse, mutect2, varscan2
- ITSN1 | c.1187G>A p.R396H | Missense Mutation (SNP) | VAF 250/498 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs779207769; called by muse, mutect2, varscan2
- JPT1 | c.65G>A p.R22Q | Missense Mutation (SNP) | VAF 147/306 reads (48%) | SIFT tolerated (0.08); PolyPhen benign (0.036); catalogued as rs1396407786, COSV59173228; called by muse, mutect2, varscan2
- KAT2A | c.1621C>T p.R541C | Missense Mutation (SNP) | VAF 160/367 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as rs782071302; called by muse, mutect2, varscan2
- KAT6B | c.6154G>A p.G2052R | Missense Mutation (SNP) | VAF 174/349 reads (50%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.895); catalogued as rs756847080; called by muse, mutect2, varscan2
- KAZN | c.917C>T p.A306V | Missense Mutation (SNP) | VAF 168/327 reads (51%) | SIFT deleterious (0.05); PolyPhen benign (0.007); catalogued as rs755820319, COSV63210399; called by muse, mutect2, varscan2
- KCNA4 | c.1286del p.G429Vfs*53 | Frame Shift Del (DEL) | VAF 184/405 reads (45%) | catalogued as rs1258313537; called by mutect2, varscan2
- KCNA4 | c.663del p.F221Lfs*21 | Frame Shift Del (DEL) | VAF 168/340 reads (49%) | catalogued as rs754892524; called by mutect2, varscan2
- KCNA6 | c.1523G>A p.R508Q | Missense Mutation (SNP) | VAF 184/403 reads (46%) | SIFT tolerated, low confidence (0.55); PolyPhen benign (0.057); catalogued as rs778896791; called by muse, mutect2, varscan2
- KCNB2 | c.128del p.G43Afs*40 | Frame Shift Del (DEL) | VAF 156/417 reads (37%) | catalogued as COSV73053085; called by mutect2, pindel, varscan2
- KCNC1 | c.937G>A p.V313I | Missense Mutation (SNP) | VAF 231/478 reads (48%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.998); catalogued as rs1305576844, COSV56394680; called by muse, mutect2, varscan2
- KCND3 | c.1889G>A p.R630Q | Missense Mutation (SNP) | VAF 242/513 reads (47%) | SIFT tolerated, low confidence (0.81); PolyPhen benign (0.039); catalogued as rs774713377, COSV56175352; called by muse, mutect2, varscan2
- KCND3 | c.948C>A p.S316R | Missense Mutation (SNP) | VAF 165/350 reads (47%) | SIFT tolerated (0.2); PolyPhen benign (0.348); catalogued as COSV56182496; called by muse, mutect2, varscan2
- KCNF1 | c.1250G>A p.R417H | Missense Mutation (SNP) | VAF 218/508 reads (43%) | SIFT tolerated (0.07); PolyPhen benign (0.379); catalogued as COSV54462706; called by muse, mutect2
- KCNG3 | c.937G>A p.G313S | Missense Mutation (SNP) | VAF 214/454 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs370971617, COSV100045291; called by muse, mutect2, varscan2
- KCNJ14 | c.517G>A p.G173S | Missense Mutation (SNP) | VAF 327/650 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs1156545913, COSV60738453, COSV60738556; called by muse, mutect2, varscan2
- KCNQ5 | c.2518G>A p.E840K | Missense Mutation (SNP) | VAF 127/244 reads (52%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.178); catalogued as rs1562230186, COSV59658525; called by muse, mutect2, varscan2
- KCNQ5 | c.2726G>A p.R909Q | Missense Mutation (SNP) | VAF 167/336 reads (50%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0.203); catalogued as rs184951305, COSV100573017; called by muse, mutect2, varscan2
- KCNT1 | c.1660C>T p.R554C (on ENST00000488444; = p.R573C on NM_020822.3) | Missense Mutation (SNP) | VAF 207/547 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.015); catalogued as rs557219607, COSV53706654; ClinVar: uncertain significance; called by muse, mutect2
- KCNV1 | c.1342C>T p.R448C | Missense Mutation (SNP) | VAF 131/290 reads (45%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.483); catalogued as rs1157202808, COSV52084721; called by muse, mutect2, varscan2
- KCNV2 | c.523G>A p.G175R | Missense Mutation (SNP) | VAF 185/542 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as rs766187569, COSV101172463, COSV66056982; called by muse, mutect2, varscan2
- KCTD12 | c.125del p.G42Afs*5 | Frame Shift Del (DEL) | VAF 273/723 reads (38%) | catalogued as COSV58524529; called by mutect2, pindel, varscan2
- KDM2A | c.2500del p.R834Vfs*3 | Frame Shift Del (DEL) | VAF 261/552 reads (47%) | catalogued as COSV58189826; called by mutect2, varscan2
- KDM4C | c.2170C>T p.R724W | Missense Mutation (SNP) | VAF 99/178 reads (56%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.912); catalogued as rs776351428, COSV67187037; called by muse, mutect2, varscan2
- KHDRBS3 | c.948C>T p.Y316= | Splice Region (SNP) | VAF 160/364 reads (44%) | catalogued as rs373585149; called by muse, mutect2, varscan2
- KIAA1217 | c.1487del p.P496Lfs*26 | Frame Shift Del (DEL) | VAF 224/495 reads (45%) | catalogued as COSV56813511; called by mutect2, pindel, varscan2
- KIAA1522 | c.2705G>A p.R902Q (on ENST00000373480 / NM_001198972.2; = p.R961Q on NM_020888.3) | Missense Mutation (SNP) | VAF 252/542 reads (46%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.957); catalogued as rs374716724; called by muse, varscan2
- KIF18B | c.1471G>A p.V491M (on ENST00000593135 / NM_001265577.2; = p.V503M on NM_001264573.2) | Missense Mutation (SNP) | VAF 133/299 reads (44%) | SIFT tolerated (0.37); PolyPhen benign (0.003); catalogued as rs769795016, COSV59274303; called by muse, varscan2
- KIFC1 | c.1723G>A p.G575S | Missense Mutation (SNP) | VAF 421/833 reads (51%) | SIFT tolerated (1); PolyPhen benign (0.015); catalogued as rs201396332, COSV65729182; called by muse, mutect2, varscan2
- KIRREL1 | c.2255G>A p.R752H | Missense Mutation (SNP) | VAF 135/243 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1474957010; called by muse, mutect2, varscan2
- KIRREL2 | c.439C>T p.R147W | Missense Mutation (SNP) | VAF 238/534 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs767203597, COSV52875861; called by muse, varscan2
- KISS1R | c.79G>A p.A27T | Missense Mutation (SNP) | VAF 363/784 reads (46%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as rs757918057; called by muse, mutect2, varscan2
- KLC2 | c.1243G>A p.A415T | Missense Mutation (SNP) | VAF 135/337 reads (40%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.63); catalogued as rs771453461; called by muse, mutect2, varscan2
- KLF7 | c.437G>A p.R146H | Missense Mutation (SNP) | VAF 242/474 reads (51%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); catalogued as rs747043061; called by muse, mutect2, varscan2
- KLHL41 | c.143G>T p.R48I | Missense Mutation (SNP) | VAF 147/331 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99500286; called by muse, mutect2, varscan2
- KMT2B | c.3230G>A p.R1077Q | Missense Mutation (SNP) | VAF 305/634 reads (48%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.978); catalogued as COSV55863591; called by muse, mutect2, varscan2
- KMT2B | c.4235del p.G1412Afs*10 | Frame Shift Del (DEL) | VAF 327/842 reads (39%) | catalogued as rs34078597; called by mutect2, pindel, varscan2
- KMT2D | c.1694C>T p.P565L | Missense Mutation (SNP) | VAF 270/575 reads (47%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.47); catalogued as rs777682865, COSV56473406; called by muse, mutect2, varscan2
- KPNA3 | c.771+1G>A p.X257_splice | Splice Site (SNP) | VAF 130/263 reads (49%) | catalogued as COSV55507483; called by muse, mutect2, varscan2
- KRT13 | c.292G>A p.G98S | Missense Mutation (SNP) | VAF 295/619 reads (48%) | SIFT tolerated (0.25); PolyPhen benign (0.018); catalogued as rs145116138; called by muse, mutect2, varscan2
- KRT14 | c.200del p.G67Afs*51 | Frame Shift Del (DEL) | VAF 281/654 reads (43%) | catalogued as rs769596857; called by mutect2, pindel, varscan2
- KRT222 | c.346G>A p.E116K | Missense Mutation (SNP) | VAF 209/459 reads (46%) | SIFT tolerated (0.08); PolyPhen benign (0.029); catalogued as rs751191563, COSV67498703; called by muse, mutect2, varscan2
- KRT3 | c.1735G>A p.G579S | Missense Mutation (SNP) | VAF 471/939 reads (50%) | SIFT tolerated (0.55); PolyPhen benign (0.022); catalogued as rs772879943, COSV58814764; called by muse, mutect2, varscan2
- KRT72 | c.1141G>A p.A381T | Missense Mutation (SNP) | VAF 192/408 reads (47%) | SIFT deleterious (0.02); PolyPhen benign (0.26); catalogued as rs368767777, COSV53374553; called by muse, mutect2
- KRT79 | c.239T>C p.L80S | Missense Mutation (SNP) | VAF 236/531 reads (44%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as rs1368877804; called by muse, mutect2, varscan2
- KRT80 | c.787G>A p.A263T | Missense Mutation (SNP) | VAF 266/576 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.84); catalogued as rs764141245, COSV100502545; called by muse, mutect2, varscan2
- KSR1 | c.233C>T p.A78V | Missense Mutation (SNP) | VAF 145/281 reads (52%) | SIFT tolerated (0.28); PolyPhen benign (0.037); catalogued as rs776835480, COSV99259102; called by muse, mutect2, varscan2
- L1CAM | c.557C>T p.T186M | Missense Mutation (SNP) | VAF 245/246 reads (100%) | SIFT tolerated (0.14); PolyPhen benign (0.37); catalogued as rs782070899, COSV62828384; called by muse, mutect2, varscan2
- L3MBTL3 | c.2057G>A p.R686H | Missense Mutation (SNP) | VAF 193/369 reads (52%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.835); catalogued as rs769544082, COSV62390054; called by muse, mutect2, varscan2
- LACTBL1 | c.611C>T p.S204L (on ENST00000618559; = p.S249L on NM_001289974.2) | Missense Mutation (SNP) | VAF 289/563 reads (51%) | SIFT tolerated (0.2); PolyPhen benign (0.007); catalogued as rs1318546041; called by muse, mutect2, varscan2
- LAMA5 | c.1219C>T p.R407C | Missense Mutation (SNP) | VAF 196/365 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs749953963; called by muse, mutect2, varscan2
- LARGE1 | c.1585G>A p.V529M | Missense Mutation (SNP) | VAF 236/492 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs146923365; called by muse, varscan2
- LARP1 | c.2702G>A p.R901Q (on ENST00000518297 / NM_033551.3; = p.R824Q on NM_015315.5 and 6 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 124/291 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs757450704, COSV60427870; called by muse, mutect2, varscan2
- LARP4B | c.920G>A p.R307Q | Missense Mutation (SNP) | VAF 140/273 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs866154645, COSV60223537; called by muse, mutect2, varscan2
- LCE2A | c.242G>A p.R81Q | Missense Mutation (SNP) | VAF 238/522 reads (46%) | SIFT tolerated, low confidence (0.49); PolyPhen benign (0.014); catalogued as rs753692865, COSV64226821; called by muse, mutect2, varscan2
- LDLR | c.1562C>T p.A521V | Missense Mutation (SNP) | VAF 122/253 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as rs770696696, CM091471; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- LEFTY1 | c.454G>A p.V152I | Missense Mutation (SNP) | VAF 268/640 reads (42%) | SIFT tolerated (0.36); PolyPhen benign (0.005); catalogued as rs1410615103; called by muse, mutect2, varscan2
- LHFPL5 | c.565G>A p.A189T | Missense Mutation (SNP) | VAF 208/401 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.604); catalogued as rs376479168; called by muse, mutect2, varscan2
- LIFR | c.2984C>A p.P995H | Missense Mutation (SNP) | VAF 144/305 reads (47%) | SIFT tolerated (0.54); PolyPhen benign (0.315); catalogued as COSV54691142; called by muse, mutect2, varscan2
- LILRA1 | c.72G>A p.G24= | Splice Region (SNP) | VAF 106/262 reads (40%) | catalogued as rs765286954, COSV99251940; called by muse, mutect2, varscan2
- LILRA4 | c.889G>A p.G297S | Missense Mutation (SNP) | VAF 247/522 reads (47%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as rs750275949, COSV99392780; called by muse, mutect2, varscan2
- LILRB4 | c.289C>T p.R97C | Missense Mutation (SNP) | VAF 321/595 reads (54%) | SIFT deleterious (0); PolyPhen benign (0.095); catalogued as rs145519196, COSV54409351; called by muse, mutect2, varscan2
- LINC02210-CRHR1 | c.350G>A p.R117H | Missense Mutation (SNP) | VAF 270/530 reads (51%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.982); catalogued as rs369219844; called by muse, mutect2, varscan2
- LINGO4 | c.1253C>T p.S418L | Missense Mutation (SNP) | VAF 307/603 reads (51%) | SIFT deleterious (0.02); PolyPhen benign (0.37); catalogued as rs748289467; called by muse, mutect2, varscan2
- LIPG | c.1291C>T p.R431C | Missense Mutation (SNP) | VAF 169/349 reads (48%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.939); catalogued as rs536799767, COSV54296081; called by muse, mutect2, varscan2
- LKAAEAR1 | c.227C>A p.A76D | Missense Mutation (SNP) | VAF 456/903 reads (50%) | SIFT tolerated (0.12); PolyPhen benign (0.279); catalogued as rs1055207954; called by muse, mutect2, varscan2
- LMAN1L | c.679G>A p.G227S | Missense Mutation (SNP) | VAF 240/552 reads (43%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as rs202021967; called by muse, mutect2, varscan2
- LMAN2L | c.742G>A p.G248S | Missense Mutation (SNP) | VAF 127/278 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs748501432; called by muse, mutect2, varscan2
- LMLN2 | c.964C>T p.R322* | Nonsense Mutation (SNP) | VAF 157/348 reads (45%) | catalogued as rs987609587; called by muse, mutect2, varscan2
- LMX1B | c.559G>A p.V187M | Missense Mutation (SNP) | VAF 160/300 reads (53%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.616); catalogued as rs765969991; called by muse, mutect2, varscan2
- LONP1 | c.1939G>A p.E647K | Missense Mutation (SNP) | VAF 177/330 reads (54%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.763); catalogued as rs149596661; called by muse, mutect2, varscan2
- LOXHD1 | c.5474G>A p.R1825Q (on ENST00000642948; = p.R1763Q on NM_144612.7) | Missense Mutation (SNP) | VAF 180/373 reads (48%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.559); catalogued as rs771185362; called by muse, mutect2, varscan2
- LPA | c.209+1G>A p.X70_splice | Splice Site (SNP) | VAF 55/116 reads (47%) | catalogued as rs533200556, COSV60300564; called by muse, mutect2, varscan2
- LRP1 | c.8914C>T p.R2972W | Missense Mutation (SNP) | VAF 163/352 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); catalogued as rs749876967, COSV54514789; called by muse, mutect2
- LRP1 | c.11062G>A p.E3688K | Missense Mutation (SNP) | VAF 148/285 reads (52%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.983); catalogued as rs201541007; called by muse, mutect2, varscan2
- LRP1B | c.10454del p.N3485Tfs*33 | Frame Shift Del (DEL) | VAF 111/301 reads (37%) | catalogued as rs79925984; called by mutect2, pindel, varscan2
- LRP2 | c.13832C>T p.A4611V | Missense Mutation (SNP) | VAF 172/355 reads (48%) | SIFT tolerated (0.41); PolyPhen benign (0.003); catalogued as rs529198764, COSV55540455; called by muse, mutect2, varscan2
- LRP2 | c.4478C>T p.A1493V | Missense Mutation (SNP) | VAF 135/271 reads (50%) | SIFT tolerated (0.25); PolyPhen benign (0.017); catalogued as rs748382645, COSV55565358; called by muse, varscan2
- LRP4 | c.5498G>A p.R1833Q | Missense Mutation (SNP) | VAF 187/432 reads (43%) | SIFT tolerated, low confidence (0.05); PolyPhen probably damaging (0.921); catalogued as rs771256759, COSV66135635; called by muse, mutect2, varscan2
- LRP4 | c.322C>T p.R108W | Missense Mutation (SNP) | VAF 128/276 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as rs775191643; called by muse, mutect2, varscan2
- LRRC14 | c.218G>A p.R73H | Missense Mutation (SNP) | VAF 291/549 reads (53%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.686); catalogued as rs1337625543, COSV52879975; called by muse, mutect2, varscan2
- LRRC27 | c.851C>T p.T284M | Missense Mutation (SNP) | VAF 216/440 reads (49%) | SIFT deleterious (0.01); PolyPhen benign (0.183); catalogued as rs112727561; called by muse, mutect2, varscan2
- LRRC37A3 | c.599G>A p.R200Q | Missense Mutation (SNP) | VAF 172/708 reads (24%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as rs1193621508; called by muse, varscan2
- LRRC43 | c.1820_1822del p.K607del | In Frame Del (DEL) | VAF 136/316 reads (43%) | catalogued as rs770573768; called by pindel, varscan2
- LRRC49 | c.310G>A p.V104I | Missense Mutation (SNP) | VAF 83/177 reads (47%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.805); catalogued as rs767471553; called by muse, mutect2, varscan2
- LRRC4B | c.1858G>A p.V620M | Missense Mutation (SNP) | VAF 395/795 reads (50%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.557); catalogued as rs1276337308, COSV100976105; called by muse, mutect2, varscan2
- LRRC4C | c.1727C>T p.T576M | Missense Mutation (SNP) | VAF 163/337 reads (48%) | SIFT tolerated, low confidence (0.05); PolyPhen possibly damaging (0.54); catalogued as rs201412968, COSV53425400, COSV53430470; called by muse, varscan2
- LRRC7 | c.1480C>T p.R494C (on ENST00000651989 / NM_001370785.2; = p.R461C on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 115/212 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs765562100; called by muse, mutect2, varscan2
- LRWD1 | c.1900G>A p.A634T | Missense Mutation (SNP) | VAF 195/380 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as rs150396748; called by muse, mutect2, varscan2
- LSM10 | c.79C>T p.R27W | Missense Mutation (SNP) | VAF 233/449 reads (52%) | SIFT tolerated (0.15); PolyPhen benign (0.417); catalogued as rs943465242; called by muse, varscan2
- LSM11 | c.974G>A p.R325H | Missense Mutation (SNP) | VAF 209/429 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.959); catalogued as rs769770410, COSV53848901; called by muse, mutect2, varscan2
- LZIC | c.570del p.K190Nfs*16 | Frame Shift Del (DEL) | VAF 137/322 reads (43%) | catalogued as rs753028254; called by mutect2, pindel, varscan2
- LZTS1 | c.703G>A p.G235R | Missense Mutation (SNP) | VAF 249/518 reads (48%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.518); catalogued as rs1259821365; called by muse, mutect2, varscan2
- MAG | c.1153G>A p.E385K | Missense Mutation (SNP) | VAF 236/480 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); catalogued as rs372192843; called by muse, mutect2, varscan2
- MAGEB6B | c.47G>A p.R16Q | Missense Mutation (SNP) | VAF 124/124 reads (100%) | SIFT tolerated (0.3); PolyPhen benign (0.001); catalogued as rs1346788256, COSV69689992; called by muse, mutect2, varscan2
- MAGI2 | c.4112C>T p.A1371V | Missense Mutation (SNP) | VAF 101/169 reads (60%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0); catalogued as rs13438363; called by muse, mutect2, varscan2
- MALRD1 | c.1342G>A p.A448T | Missense Mutation (SNP) | VAF 180/389 reads (46%) | SIFT tolerated (0.58); PolyPhen benign (0.015); catalogued as rs1282298965; called by muse, mutect2, varscan2
- MALSU1 | c.424G>A p.V142I | Missense Mutation (SNP) | VAF 99/249 reads (40%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs747613839, COSV54978160; called by muse, mutect2, varscan2
- MAMDC4 | c.226C>T p.R76W | Missense Mutation (SNP) | VAF 255/598 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.959); catalogued as rs1383747941, COSV56031702; called by muse, mutect2, varscan2
- MAN1B1 | c.557C>T p.T186I | Missense Mutation (SNP) | VAF 327/564 reads (58%) | SIFT tolerated (0.19); PolyPhen benign (0.01); catalogued as rs1488519885; called by muse, mutect2, varscan2
- MAN2A2 | c.1490C>T p.A497V | Missense Mutation (SNP) | VAF 209/457 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs144478704; called by muse, mutect2, varscan2
- MAN2A2 | c.2183G>A p.R728H | Missense Mutation (SNP) | VAF 268/601 reads (45%) | SIFT tolerated (0.12); PolyPhen benign (0.007); catalogued as rs146996561; called by muse, mutect2, varscan2
- MAN2B2 | c.1991G>A p.R664Q | Missense Mutation (SNP) | VAF 125/265 reads (47%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.87); catalogued as rs569059179; called by muse, mutect2, varscan2
- MAN2C1 | c.2624C>T p.A875V | Missense Mutation (SNP) | VAF 195/413 reads (47%) | SIFT tolerated (0.36); PolyPhen benign (0.084); catalogued as rs778458430, COSV51237082; called by muse, mutect2, varscan2
- MAP1S | c.1288G>A p.V430M | Missense Mutation (SNP) | VAF 287/682 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs773801022; called by muse, mutect2
- MAP2K5 | c.1306C>T p.R436W (on ENST00000178640 / NM_145160.3; = p.R426W on NM_002757.4) | Missense Mutation (SNP) | VAF 219/442 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as rs762647820; called by muse, mutect2, varscan2
- MAP3K9 | c.424G>A p.A142T | Missense Mutation (SNP) | VAF 146/294 reads (50%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as rs961518449; called by muse, mutect2, varscan2
- MAPK7 | c.478C>T p.R160C | Missense Mutation (SNP) | VAF 205/416 reads (49%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.748); catalogued as rs748679283; called by muse, mutect2, varscan2
- MAPK8IP3 | c.1912G>A p.A638T | Missense Mutation (SNP) | VAF 152/348 reads (44%) | SIFT tolerated (0.27); PolyPhen benign (0.009); catalogued as rs763939482, COSV51726366; called by muse, varscan2
- MARCHF1 | c.680G>A p.R227H (on ENST00000274056; = p.R210H on NM_017923.4) | Missense Mutation (SNP) | VAF 177/375 reads (47%) | SIFT deleterious (0.05); PolyPhen benign (0.158); catalogued as rs779641825; called by muse, mutect2, varscan2
- MARF1 | c.343C>T p.R115C | Missense Mutation (SNP) | VAF 261/577 reads (45%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.001); catalogued as rs201651611; called by muse, mutect2, varscan2
- MATN2 | c.529G>A p.V177M | Missense Mutation (SNP) | VAF 172/358 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs774927507, COSV54714909; called by muse, varscan2
- MATN2 | c.554G>A p.R185Q | Missense Mutation (SNP) | VAF 176/357 reads (49%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as rs200270504; called by muse, varscan2
- MBOAT2 | c.128G>A p.R43Q | Missense Mutation (SNP) | VAF 191/395 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1471364240, COSV60007642; called by muse, mutect2, varscan2
- MC1R | c.562G>A p.V188I | Missense Mutation (SNP) | VAF 286/578 reads (49%) | SIFT tolerated (0.08); PolyPhen benign (0.179); catalogued as rs774680166, COSV59626514; called by muse, mutect2, varscan2
- MCCC2 | c.385G>T p.V129L | Missense Mutation (SNP) | VAF 116/222 reads (52%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.003); catalogued as COSV60157586; called by muse, mutect2, varscan2
- MCM2 | c.1541G>A p.R514H | Missense Mutation (SNP) | VAF 114/240 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1273687863; called by muse, varscan2
- MCM2 | c.1907G>A p.R636H | Missense Mutation (SNP) | VAF 104/215 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs768322698; called by muse, mutect2, varscan2
- MCM3 | c.454G>A p.V152I (on ENST00000229854 / NM_001366374.2; = p.V142I on NM_002388.6 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 140/280 reads (50%) | SIFT tolerated (0.24); PolyPhen benign (0.202); catalogued as rs1033238760, COSV57719478; called by muse, mutect2, varscan2
- MDC1 | c.5869C>T p.R1957C | Missense Mutation (SNP) | VAF 139/290 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as rs770859881; called by muse, mutect2, varscan2
- MDH1 | c.708G>T p.K236N | Missense Mutation (SNP) | VAF 130/273 reads (48%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.927); catalogued as COSV51862786; called by mutect2, varscan2
- MDN1 | c.4616G>A p.R1539Q | Missense Mutation (SNP) | VAF 84/186 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65520068; called by muse, mutect2, varscan2
- MED1 | c.4064G>A p.R1355H | Missense Mutation (SNP) | VAF 152/333 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as rs771798336; called by muse, mutect2, varscan2
- MEF2B | c.757G>A p.G253R | Missense Mutation (SNP) | VAF 159/344 reads (46%) | SIFT deleterious (0.01); PolyPhen benign (0.014); catalogued as rs750716565; called by muse, mutect2, varscan2
- MEF2D | c.1447C>T p.R483W | Missense Mutation (SNP) | VAF 281/548 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs752408015, COSV61730368; called by muse, mutect2, varscan2
- MEGF10 | c.2671C>T p.P891S | Missense Mutation (SNP) | VAF 154/337 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.899); catalogued as rs754183529; called by muse, mutect2, varscan2
- MEGF6 | c.4445G>A p.G1482E | Missense Mutation (SNP) | VAF 326/609 reads (54%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.855); catalogued as rs1202873987; called by muse, mutect2, varscan2
- MEIOB | c.1del p.M1? | Frame Shift Del (DEL) | VAF 78/225 reads (35%) | catalogued as rs756894401; called by mutect2, pindel, varscan2
- MEIS2 | c.562G>A p.V188I (on ENST00000561208 / NM_170675.5; = p.V175I on NM_002399.3) | Missense Mutation (SNP) | VAF 177/361 reads (49%) | SIFT deleterious (0.04); PolyPhen benign (0.268); catalogued as rs762490597; called by muse, mutect2, varscan2
- METTL21A | c.535C>T p.R179W | Missense Mutation (SNP) | VAF 154/352 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs374826319; called by muse, mutect2, varscan2
- METTL7B | c.153G>A p.M51I | Missense Mutation (SNP) | VAF 209/445 reads (47%) | SIFT deleterious (0.02); PolyPhen benign (0.062); catalogued as COSV57692121; called by muse, mutect2, varscan2
- MFGE8 | c.1130G>A p.R377H | Missense Mutation (SNP) | VAF 198/411 reads (48%) | SIFT deleterious (0.03); PolyPhen benign (0.177); catalogued as rs568619975; called by muse, mutect2, varscan2
- MFHAS1 | c.1898G>A p.R633H | Missense Mutation (SNP) | VAF 230/465 reads (49%) | SIFT tolerated (0.55); PolyPhen benign (0.001); catalogued as COSV52284172; called by muse, mutect2, varscan2
- MFSD2B | c.437C>T p.T146M | Missense Mutation (SNP) | VAF 243/489 reads (50%) | SIFT tolerated (0.13); PolyPhen benign (0.028); catalogued as rs756008102; called by muse, mutect2, varscan2
- MGAT4B | c.1460G>A p.R487H | Missense Mutation (SNP) | VAF 173/373 reads (46%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as rs748605549, COSV99482332; called by muse, mutect2, varscan2
- MGLL | c.491C>T p.A164V (on ENST00000398104 / NM_001003794.2; = p.A174V on NM_007283.6) | Missense Mutation (SNP) | VAF 150/291 reads (52%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.548); catalogued as rs374353919; called by muse, mutect2, varscan2
- MGLL | c.392C>T p.T131M (on ENST00000398104 / NM_001003794.2; = p.T141M on NM_007283.6) | Missense Mutation (SNP) | VAF 171/340 reads (50%) | SIFT deleterious (0); PolyPhen benign (0.271); catalogued as rs773416847; called by muse, varscan2
- MINAR1 | c.337C>T p.R113C | Missense Mutation (SNP) | VAF 194/402 reads (48%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as rs775338460, COSV59582058; called by muse, mutect2, varscan2
- MLIP | c.1306G>A p.A436T | Missense Mutation (SNP) | VAF 96/204 reads (47%) | SIFT tolerated (0.48); PolyPhen benign (0.006); catalogued as rs145131028; called by muse, mutect2, varscan2
- MLLT10 | c.487C>T p.R163* | Nonsense Mutation (SNP) | VAF 127/246 reads (52%) | catalogued as rs1179221232, COSV57004712; called by muse, varscan2
- MMEL1 | c.700G>A p.D234N | Missense Mutation (SNP) | VAF 228/491 reads (46%) | SIFT tolerated (0.73); PolyPhen benign (0.007); catalogued as rs372890618; called by muse, mutect2, varscan2
- MMP7 | c.524C>T p.T175M | Missense Mutation (SNP) | VAF 154/340 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.776); catalogued as rs542899524, COSV52772100; called by muse, varscan2
- MON2 | c.556C>T p.R186* | Nonsense Mutation (SNP) | VAF 97/172 reads (56%) | catalogued as rs1379822048, COSV54803143; called by muse, mutect2, varscan2
- MORC2 | c.32G>A p.R11Q | Missense Mutation (SNP) | VAF 146/298 reads (49%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.517); catalogued as rs1034098965; called by muse, mutect2, varscan2
- MPEG1 | c.1915C>T p.R639W | Missense Mutation (SNP) | VAF 212/417 reads (51%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.642); catalogued as rs369599067; called by muse, mutect2, varscan2
- MPRIP | c.1837C>T p.R613C | Missense Mutation (SNP) | VAF 233/489 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.543); catalogued as rs1175028801; called by muse, mutect2, varscan2
- MRC2 | c.484G>A p.G162S | Missense Mutation (SNP) | VAF 190/402 reads (47%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.823); catalogued as rs368122647; called by muse, mutect2, varscan2
- MRGPRX1 | c.629C>T p.P210L | Missense Mutation (SNP) | VAF 219/643 reads (34%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.597); catalogued as rs760583024, COSV57109647; called by muse, mutect2, varscan2
- MRM3 | c.820G>A p.V274M | Missense Mutation (SNP) | VAF 229/453 reads (51%) | SIFT deleterious (0); PolyPhen benign (0.426); catalogued as rs761278369, COSV58680856; called by muse, mutect2, varscan2
- MROH2A | c.1973G>A p.R658Q | Missense Mutation (SNP) | VAF 64/163 reads (39%) | SIFT tolerated (0.32); PolyPhen benign (0.021); catalogued as rs1201608726; called by muse, mutect2, varscan2
- MRPL19 | c.83del p.P28Rfs*49 | Frame Shift Del (DEL) | VAF 224/480 reads (47%) | catalogued as rs1558718327, COSV62567684; called by mutect2, varscan2
- MRPL21 | c.581G>A p.R194Q | Missense Mutation (SNP) | VAF 122/280 reads (44%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs201987235, COSV62913775; called by muse, mutect2, varscan2
- MRPS18B | c.764A>G p.Q255R | Missense Mutation (SNP) | VAF 192/408 reads (47%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.025); catalogued as rs1197838687; called by muse, mutect2, varscan2
- MSANTD4 | c.230G>A p.R77Q | Missense Mutation (SNP) | VAF 172/344 reads (50%) | SIFT tolerated (0.12); PolyPhen benign (0.101); catalogued as rs1177741904; called by muse, mutect2, varscan2
- MST1R | c.418C>T p.Q140* | Nonsense Mutation (SNP) | VAF 327/619 reads (53%) | catalogued as rs1216259052, COSV56565834; called by muse, mutect2, varscan2
- MTHFR | c.757G>A p.V253I | Missense Mutation (SNP) | VAF 147/302 reads (49%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs200056619, CM127686; called by muse, mutect2, varscan2
- MTMR12 | c.2065del p.Q689Rfs*8 | Frame Shift Del (DEL) | VAF 213/424 reads (50%) | catalogued as rs1166239304; called by mutect2, varscan2
- MTSS1 | c.459del p.R155Efs*34 | Frame Shift Del (DEL) | VAF 115/268 reads (43%) | catalogued as rs1563799887; called by mutect2, pindel, varscan2
- MTSS2 | c.2012G>A p.R671Q | Missense Mutation (SNP) | VAF 369/751 reads (49%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.644); catalogued as rs374985478; called by muse, mutect2, varscan2
- MTUS2 | c.3565C>T p.R1189W (on ENST00000612955 / NM_001366650.1; = p.R168W on NM_015233.6) | Missense Mutation (SNP) | VAF 106/252 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs753762677, COSV60158423; called by muse, mutect2, varscan2
- MUC17 | c.13469C>T p.T4490M | Missense Mutation (SNP) | VAF 146/299 reads (49%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0.001); catalogued as rs534194993, COSV60292396; called by muse, mutect2, varscan2
- MUC2 | c.2413C>T p.R805W | Missense Mutation (SNP) | VAF 190/371 reads (51%) | SIFT tolerated (0.17); catalogued as rs549661080; called by muse, mutect2, varscan2
- MUC20 | c.1484C>T p.T495M | Missense Mutation (SNP) | VAF 357/1365 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs372880164; called by muse, mutect2, varscan2
- MUC21 | c.1612dup p.H538Pfs*8 | Frame Shift Ins (INS) | VAF 301/722 reads (42%) | catalogued as rs1242962833; called by mutect2, pindel, varscan2
- MUC4 | c.9215C>T p.P3072L | Missense Mutation (SNP) | VAF 220/916 reads (24%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.722); catalogued as rs774537374; called by muse, varscan2
- MUC5B | c.14862C>T p.P4954= | Splice Region (SNP) | VAF 133/279 reads (48%) | catalogued as rs113593046; called by muse, varscan2
- MYADM | c.295C>T p.R99C | Missense Mutation (SNP) | VAF 307/641 reads (48%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.916); catalogued as rs150025165; called by muse, mutect2, varscan2
2,043 further variants in this file (1,290 protein-altering or splice-affecting, 670 silent, 83 other) are not listed here.
